Somatic mutation profile of tumor specimen TCGA-AP-A056-01A (aliquot TCGA-AP-A056-01A-11W-A027-09) from TCGA case TCGA-AP-A056, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage II; Tumor grade: G3; Age at diagnosis: 64.9 years (23,707 days).
Specimen TCGA-AP-A056-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 413c7f08-8b55-42a1-86c2-5bf9c6a0a9f1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AP-A056-10A (Blood Derived Normal), aliquot TCGA-AP-A056-10A-01W-A027-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e53d1170-3c15-40a5-91a2-ca35b8efaf28

The open-access MAF lists 9,784 somatic variants for this specimen: 7,591 protein-altering or splice-affecting, 1,945 silent, 248 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6,631, Silent 1,945, Nonsense Mutation 783, Intron 115, Splice Site 79, RNA 75, Splice Region 37, Frame Shift Ins 36, 3'Flank 18, 5'Flank 15, Frame Shift Del 15, 3'UTR 14.

Variants (750 of 9,784; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGK | c.841C>T p.R281* | Nonsense Mutation (SNP) | VAF 69/230 reads (30%) | catalogued as rs387907025, CM121158, COSV62595265; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AP1S2 | c.40C>T p.R14* | Nonsense Mutation (SNP) | VAF 17/51 reads (33%) | catalogued as rs1555904878, COSV61306169; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.6610C>T p.R2204* | Nonsense Mutation (SNP) | VAF 87/271 reads (32%) | catalogued as rs752654519, COSV57326468, COSV99965912; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ARID1A | c.5965C>T p.R1989* | Nonsense Mutation (SNP) | VAF 85/265 reads (32%) | hotspot (GDC flag); catalogued as rs879255270, CM1311944, COSV61370535; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AVPR2 | c.337C>T p.R113W | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28935496, CM930063, COSV61686589; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BCS1L | c.548G>A p.R183H | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs121908577, CM070650, COSV99828974; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BRCA2 | c.1058C>A p.S353* | Nonsense Mutation (SNP) | VAF 92/327 reads (28%) | catalogued as rs769368098, COSV101204193; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CEP83 | c.1888C>T p.R630* | Nonsense Mutation (SNP) | VAF 10/180 reads (6%) | catalogued as rs1207804224, COSV51574274; ClinVar: pathogenic; called by muse, mutect2
- COL17A1 | c.433C>T p.R145* | Nonsense Mutation (SNP) | VAF 23/70 reads (33%) | catalogued as rs121912774, CM001969, COSV62225489; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COL4A5 | c.5030G>A p.R1677Q | Missense Mutation (SNP) | VAF 70/281 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs104886308, CM010201, CM113173, CM970369, COSV60366574; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- DIS3 | c.1145G>A p.R382Q | Missense Mutation (SNP) | VAF 40/110 reads (36%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.767); catalogued as rs139907646, COSV66705997; called by muse, mutect2, varscan2
- DMD | c.4729C>T p.R1577* | Nonsense Mutation (SNP) | VAF 79/214 reads (37%) | catalogued as rs863224999, CD103874, CM024590, COSV100820120, COSV63775138; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DMD | c.3940C>T p.R1314* | Nonsense Mutation (SNP) | VAF 39/106 reads (37%) | catalogued as rs5030730, CM100263, CS002446, COSV63740877; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DNAH5 | c.8030G>A p.R2677Q | Missense Mutation (SNP) | VAF 59/175 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs886043448, CM1310742, COSV54226107; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- DNMT1 | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 19/71 reads (27%) | hotspot (GDC flag); SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.995); catalogued as rs755995375, COSV61576496; called by muse, mutect2, varscan2
- EARS2 | c.1547G>A p.R516Q | Missense Mutation (SNP) | VAF 24/167 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201727231, CM123416; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- EPHA3 | c.406C>T p.R136* | Nonsense Mutation (SNP) | VAF 83/291 reads (29%) | hotspot (GDC flag); catalogued as rs770780950, COSV60693907; called by muse, mutect2, varscan2
- EXT2 | c.679G>A p.D227N (on ENST00000343631; = p.D260N on NM_000401.3) | Missense Mutation (SNP) | VAF 111/382 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs121918280, CM970453, COSV59152591; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.671G>A p.R224Q (on ENST00000281708 / NM_001349798.2; = p.R144Q on NM_018315.5) | Missense Mutation (SNP) | VAF 43/145 reads (30%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen possibly damaging (0.885); catalogued as rs752114536, COSV55904138; called by muse, mutect2, varscan2
- FH | c.1027C>T p.R343* | Nonsense Mutation (SNP) | VAF 37/135 reads (27%) | catalogued as rs121913122, CM020707, COSV63817790; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FLAD1 | c.1588C>T p.R530C | Missense Mutation (SNP) | VAF 27/169 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs771466122, CM166319, COSV52695597; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GRIN2B | c.1672G>A p.V558I | Missense Mutation (SNP) | VAF 92/305 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.746); catalogued as rs1057519004, COSV74206831; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, varscan2
- KANSL1 | c.1816C>T p.R606* | Nonsense Mutation (SNP) | VAF 29/82 reads (35%) | catalogued as rs281865469, CM124328, COSV52265197, COSV52273519; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KCNQ1 | c.1552C>T p.R518* | Nonsense Mutation (SNP) | VAF 4/26 reads (15%) | catalogued as rs17215500, CM057185, CM992171; ClinVar: pathogenic / benign / uncertain significance; called by mutect2, varscan2
- KMT2A | c.3451C>T p.R1151* | Nonsense Mutation (SNP) | VAF 51/386 reads (13%) | catalogued as rs868985556, COSV63289633; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 8/37 reads (22%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- MIP | c.97C>T p.R33C | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.835); catalogued as rs864309693, CM074358, COSV57788643; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MSH3 | c.1534G>T p.E512* | Nonsense Mutation (SNP) | VAF 82/238 reads (34%) | catalogued as rs1379605717, COSV54149476; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MTM1 | c.1210G>A p.E404K | Missense Mutation (SNP) | VAF 41/128 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.355); catalogued as rs781933660, CM970997, COSV100080340, COSV60336339; ClinVar: pathogenic; called by muse, mutect2
- MYO18B | c.6433C>T p.R2145* | Nonsense Mutation (SNP) | VAF 50/226 reads (22%) | catalogued as rs753585568, COSV59141498; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NBEA | c.6637C>T p.R2213* | Nonsense Mutation (SNP) | VAF 17/68 reads (25%) | catalogued as rs878853169, COSV59803600; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NONO | c.1093C>T p.R365* | Nonsense Mutation (SNP) | VAF 14/38 reads (37%) | catalogued as rs869025345, CM1512177, COSV52137834; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NPHS1 | c.1905C>T p.S635= | Silent (SNP) | VAF 16/40 reads (40%) | catalogued as rs386833896, CS020541, COSV62289009; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NSD1 | c.5950C>T p.R1984* | Nonsense Mutation (SNP) | VAF 34/415 reads (8%) | catalogued as rs797045057, CM043040, CM051589, COSV61774888; ClinVar: pathogenic; called by muse, mutect2
- OTC | c.275G>A p.R92Q | Missense Mutation (SNP) | VAF 41/120 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs66550389, CM062966, CM062967, CM910275, COSV50000649, COSV50002957; ClinVar: pathogenic; called by muse, varscan2
- PIK3CA | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 59/195 reads (30%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs121913287, CM126688, COSV55874568, COSV55924241; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3062A>G p.Y1021C | Missense Mutation (SNP) | VAF 45/163 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121913288, CM126695, COSV55882161, COSV55997924; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3R1 | c.1042C>T p.R348* (on ENST00000521381 / NM_181523.3; = p.R78* on NM_181504.4) | Nonsense Mutation (SNP) | VAF 22/70 reads (31%) | hotspot (GDC flag); catalogued as rs1057520690, COSV57123475; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3R1 | c.1945C>T p.R649W (on ENST00000521381 / NM_181523.3; = p.R379W on NM_181504.4) | Missense Mutation (SNP) | VAF 45/157 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs397515453, CM136430, COSV57134498; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PKHD1 | c.9719G>A p.R3240Q | Missense Mutation (SNP) | VAF 55/235 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs146649803, CM051180, CM051181, COSV61861681; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PLA2G6 | c.1627C>T p.R543C | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs753874848, COSV59271808; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PLCE1 | c.4451C>T p.S1484L | Missense Mutation (SNP) | VAF 39/150 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912605, CM066177, COSV53350732, COSV99593752; ClinVar: pathogenic; called by muse, mutect2, varscan2
- POLE | c.1231G>T p.V411L | Missense Mutation (SNP) | VAF 133/255 reads (52%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519945, COSV57676103, COSV57677068, COSV57683938; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PPP2R1A | c.773G>A p.R258H | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.375); catalogued as rs863225094, CM157465, COSV59042809; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PRPH2 | c.469G>A p.D157N | Missense Mutation (SNP) | VAF 46/141 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs61755787, CM951117, COSV57837952; ClinVar: likely pathogenic / not provided; called by muse, varscan2
- PTEN | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 90/262 reads (34%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs121909229, CM981670, CM991081, COSV64288376, COSV64288604, COSV64290765, COSV64291054; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- SCN1A | c.4547C>T p.S1516L (on ENST00000303395 / NM_001202435.3; = p.S1505L on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/117 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs139300715, CM024310, CM1511239, COSV57665028; ClinVar: uncertain significance / likely benign / likely pathogenic; called by muse, mutect2, varscan2
- SELENON | c.1427C>T p.S476L | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs368377980, COSV62524851; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- TARBP2 | c.571G>T p.E191* (on ENST00000266987 / NM_134323.2; = p.E170* on NM_004178.4) | Nonsense Mutation (SNP) | VAF 38/107 reads (36%) | hotspot (GDC flag); catalogued as COSV57199177; called by muse, mutect2, varscan2
- TCF4 | c.520C>T p.R174* | Nonsense Mutation (SNP) | VAF 44/125 reads (35%) | catalogued as rs878853149, CM120282, COSV61890253; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TNNI3 | c.574C>T p.R192C | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs727503499, CM113585, COSV52572608; ClinVar: pathogenic; called by muse, mutect2, varscan2
- VPS13B | c.5920C>T p.R1974* | Nonsense Mutation (SNP) | VAF 34/129 reads (26%) | catalogued as rs180177365, CM062025, COSV62149913; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- A1CF | c.806C>T p.A269V | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV50985594; called by muse, mutect2, varscan2
- A2M | c.2894T>G p.L965R | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59389679; called by muse, mutect2, varscan2
- A2M | c.337G>T p.E113* | Nonsense Mutation (SNP) | VAF 22/71 reads (31%) | catalogued as COSV59388760, COSV59389701; called by muse, mutect2, varscan2
- A2ML1 | c.1328G>A p.R443Q | Missense Mutation (SNP) | VAF 51/179 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs142219499; ClinVar: likely benign; called by muse, mutect2, varscan2
- AACS | c.1008G>T p.M336I | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV55538779; called by muse, mutect2, varscan2
- AADACL3 | c.473A>C p.K158T | Missense Mutation (SNP) | VAF 111/345 reads (32%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.784); catalogued as COSV60199825; called by muse, mutect2, varscan2
- AARS2 | c.1051C>T p.R351C | Missense Mutation (SNP) | VAF 33/116 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs766485554, COSV55116456; called by muse, mutect2, varscan2
- AASDH | c.3291A>C p.Q1097H | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV52708357; called by muse, mutect2, varscan2
- AASDH | c.737T>C p.V246A | Missense Mutation (SNP) | VAF 48/136 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as COSV52708369; called by muse, mutect2, varscan2
- ABAT | c.928C>T p.R310W | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs757076760, COSV51620440; called by muse, mutect2, varscan2
- ABCA10 | c.3844T>C p.F1282L | Missense Mutation (SNP) | VAF 67/179 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.33); catalogued as COSV52226358; called by muse, mutect2, varscan2
- ABCA10 | c.3032A>G p.E1011G | Missense Mutation (SNP) | VAF 138/440 reads (31%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV52226377; called by muse, mutect2, varscan2
- ABCA10 | c.3031G>A p.E1011K | Missense Mutation (SNP) | VAF 138/440 reads (31%) | SIFT tolerated (0.74); PolyPhen benign (0.158); catalogued as COSV52226398; called by muse, mutect2, varscan2
- ABCA10 | c.2287C>T p.R763C | Missense Mutation (SNP) | VAF 51/175 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs200565917, COSV52222412; called by muse, mutect2, varscan2
- ABCA10 | c.1529G>T p.R510I | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); catalogued as COSV52219460; called by muse, varscan2
- ABCA12 | c.7401T>G p.F2467L (on ENST00000272895 / NM_173076.3; = p.F2149L on NM_015657.3) | Missense Mutation (SNP) | VAF 44/117 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.672); catalogued as COSV55967598; called by muse, mutect2, varscan2
- ABCA12 | c.6367C>A p.L2123I (on ENST00000272895 / NM_173076.3; = p.L1805I on NM_015657.3) | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT tolerated (0.16); PolyPhen probably damaging (1); catalogued as rs746428433, COSV55967612; called by muse, mutect2, varscan2
- ABCA12 | c.5728G>T p.D1910Y (on ENST00000272895 / NM_173076.3; = p.D1592Y on NM_015657.3) | Missense Mutation (SNP) | VAF 81/292 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55967627; called by muse, varscan2
- ABCA12 | c.5600G>T p.R1867I (on ENST00000272895 / NM_173076.3; = p.R1549I on NM_015657.3) | Missense Mutation (SNP) | VAF 38/135 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.744); catalogued as COSV55967642; called by muse, varscan2
- ABCA12 | c.5573A>C p.K1858T (on ENST00000272895 / NM_173076.3; = p.K1540T on NM_015657.3) | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.161); catalogued as COSV55967653, COSV99792391; called by muse, varscan2
- ABCA12 | c.5485G>A p.D1829N (on ENST00000272895 / NM_173076.3; = p.D1511N on NM_015657.3) | Missense Mutation (SNP) | VAF 30/116 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV55967666; called by muse, mutect2, varscan2
- ABCA12 | c.1312G>A p.E438K (on ENST00000272895 / NM_173076.3; = p.E120K on NM_015657.3) | Missense Mutation (SNP) | VAF 51/145 reads (35%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs562998767, COSV55967677; called by muse, mutect2, varscan2
- ABCA12 | c.179G>A p.R60Q | Missense Mutation (SNP) | VAF 50/154 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs762065937, CM130513, COSV55948982; called by muse, mutect2, varscan2
- ABCA13 | c.1503G>T p.K501N | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.117); catalogued as COSV70036126; called by muse, mutect2, varscan2
- ABCA13 | c.2069A>C p.Y690S | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70036235; called by muse, mutect2, varscan2
- ABCA13 | c.6978G>T p.M2326I | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV71291486; called by muse, mutect2, varscan2
- ABCA4 | c.4351C>T p.P1451S | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as COSV64675553; called by muse, mutect2, varscan2
- ABCA5 | c.4316G>A p.R1439Q | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369202022; called by muse, mutect2, varscan2
- ABCA5 | c.1334G>T p.R445I | Missense Mutation (SNP) | VAF 52/163 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as rs776278452, COSV67017350; called by muse, varscan2
- ABCA5 | c.748G>A p.E250K | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.951); catalogued as COSV101201128; called by muse, varscan2
- ABCA5 | c.60G>T p.K20N | Missense Mutation (SNP) | VAF 9/147 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67016490, COSV67018709; called by muse, mutect2
- ABCA6 | c.3669G>T p.K1223N | Missense Mutation (SNP) | VAF 31/118 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.103); catalogued as COSV52641658; called by muse, mutect2, varscan2
- ABCA6 | c.2593G>A p.A865T | Missense Mutation (SNP) | VAF 40/138 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.063); catalogued as rs756114521, COSV52641162; called by muse, mutect2
- ABCA8 | c.83G>T p.R28I | Missense Mutation (SNP) | VAF 56/206 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.441); catalogued as COSV52207065; called by muse, mutect2, varscan2
- ABCA9 | c.2576A>C p.K859T | Missense Mutation (SNP) | VAF 50/161 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV60628169; called by muse, mutect2, varscan2
- ABCA9 | c.1292G>A p.R431Q | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (0.47); PolyPhen benign (0.01); catalogued as rs756457606, COSV60626563; called by muse, varscan2
- ABCB1 | c.2135T>C p.V712A | Missense Mutation (SNP) | VAF 38/147 reads (26%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.709); catalogued as rs1226611649, COSV55956937; called by muse, mutect2, varscan2
- ABCB10 | c.1151T>C p.V384A | Missense Mutation (SNP) | VAF 49/160 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.129); catalogued as COSV60622469; called by muse, mutect2, varscan2
- ABCB11 | c.3365G>A p.S1122N | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.977); catalogued as rs1016053414, COSV55595798; called by muse, mutect2, varscan2
- ABCB11 | c.527A>C p.K176T | Missense Mutation (SNP) | VAF 48/136 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.784); catalogued as COSV55595819; called by muse, mutect2, varscan2
- ABCB4 | c.3468A>C p.K1156N (on ENST00000265723 / NM_018849.3; = p.K1149N on NM_000443.4) | Missense Mutation (SNP) | VAF 75/312 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.814); catalogued as COSV55938450; called by muse, mutect2, varscan2
- ABCB4 | c.3274A>G p.T1092A | Missense Mutation (SNP) | VAF 33/176 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV55938466; called by muse, mutect2, varscan2
- ABCB4 | c.823G>T p.E275* | Nonsense Mutation (SNP) | VAF 49/169 reads (29%) | catalogued as COSV55938484; called by muse, varscan2
- ABCB4 | c.754G>A p.A252T | Missense Mutation (SNP) | VAF 54/170 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV55938503; called by muse, varscan2
- ABCB5 | c.450G>T p.Q150H | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51715082; called by muse, mutect2, varscan2
- ABCB5 | c.1179C>A p.F393L | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as COSV51715089; called by muse, mutect2, varscan2
- ABCB5 | c.2626-2A>C p.X876_splice (on ENST00000404938 / NM_001163941.2; = p.X431_splice on NM_178559.6) | Splice Site (SNP) | VAF 16/94 reads (17%) | catalogued as COSV51702720, COSV99328320; called by muse, varscan2
- ABCB5 | c.3524A>G p.K1175R (on ENST00000404938 / NM_001163941.2; = p.K730R on NM_178559.6) | Missense Mutation (SNP) | VAF 51/161 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.422); catalogued as COSV51715097; called by muse, mutect2, varscan2
- ABCB7 | c.2169G>T p.K723N (on ENST00000373394 / NM_001271696.3; = p.K724N on NM_004299.6) | Missense Mutation (SNP) | VAF 67/214 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.031); catalogued as COSV53721769; called by muse, mutect2, varscan2
- ABCB7 | c.1877A>G p.D626G (on ENST00000373394 / NM_001271696.3; = p.D627G on NM_004299.6) | Missense Mutation (SNP) | VAF 38/137 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.05); catalogued as COSV53721779; called by muse, mutect2, varscan2
- ABCB7 | c.203G>T p.R68I (on ENST00000373394 / NM_001271696.3; = p.R69I on NM_004299.6) | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); catalogued as COSV53721792; called by muse, mutect2, varscan2
- ABCB9 | c.1124T>C p.M375T | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as rs1361679380, COSV54893139; called by muse, mutect2, varscan2
- ABCC11 | c.1196C>T p.A399V | Missense Mutation (SNP) | VAF 35/120 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs374130441; called by muse, mutect2, varscan2
- ABCC12 | c.2425G>A p.A809T | Missense Mutation (SNP) | VAF 44/131 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs776302423, COSV60916050; called by muse, mutect2, varscan2
- ABCC12 | c.2008G>T p.E670* | Nonsense Mutation (SNP) | VAF 24/91 reads (26%) | catalogued as COSV60916057, COSV60916782; called by muse, mutect2, varscan2
- ABCC2 | c.2647G>A p.D883N | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs911797034, COSV64987296; called by muse, mutect2, varscan2
- ABCC2 | c.2933C>T p.S978L | Missense Mutation (SNP) | VAF 58/198 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs763988128, COSV64984835; called by muse, mutect2, varscan2
- ABCC2 | c.3628C>T p.R1210C | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs754558286, COSV64987304; called by muse, mutect2, varscan2
- ABCC4 | c.3197A>C p.K1066T | Missense Mutation (SNP) | VAF 152/479 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as rs151127848; called by muse, mutect2, varscan2
- ABCC4 | c.346A>G p.I116V | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as COSV65315686; called by muse, mutect2, varscan2
- ABCC5 | c.3799C>T p.R1267* | Nonsense Mutation (SNP) | VAF 51/120 reads (43%) | catalogued as COSV55593485; called by muse, varscan2
- ABCC6 | c.3704G>A p.R1235Q | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs138700741; called by muse, mutect2, varscan2
- ABCC8 | c.1021C>A p.L341I | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT tolerated (0.28); PolyPhen benign (0.011); catalogued as COSV56846039, COSV56852803; called by muse, mutect2, varscan2
- ABCF3 | c.839C>T p.A280V | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs376213461; called by muse, mutect2, varscan2
- ABCG1 | c.1977C>A p.F659L | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV59207650; called by muse, mutect2, varscan2
- ABHD13 | c.754A>C p.K252Q | Missense Mutation (SNP) | VAF 38/140 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.127); catalogued as COSV65535233; called by muse, mutect2, varscan2
- ABHD16A | c.350G>A p.G117D | Missense Mutation (SNP) | VAF 31/157 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.789); catalogued as COSV65452170; called by muse, mutect2, varscan2
- ABHD16A | c.232G>A p.A78T | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.392); catalogued as rs745835378, COSV65452176; called by muse, mutect2, varscan2
- ABHD17B | c.733G>A p.A245T | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.166); catalogued as rs373175774; called by muse, mutect2, varscan2
- ABHD4 | c.832C>T p.R278* | Nonsense Mutation (SNP) | VAF 24/90 reads (27%) | catalogued as rs371651543, COSV53530174, COSV53530202; called by muse, mutect2, varscan2
- ABI2 | c.145G>T p.E49* | Nonsense Mutation (SNP) | VAF 31/120 reads (26%) | catalogued as COSV53691103; called by muse, mutect2, varscan2
- ABI3BP | c.2206A>G p.T736A | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV52543904; called by muse, mutect2, varscan2
- ABI3BP | c.941A>G p.E314G | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV52543932; called by muse, mutect2, varscan2
- ABI3BP | c.940G>A p.E314K | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); catalogued as rs756545296, COSV52527014; called by muse, mutect2, varscan2
- ABI3BP | c.476G>A p.R159H | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs201046479, COSV52532017; called by muse, mutect2
- ABL2 | c.3073G>A p.A1025T (on ENST00000502732 / NM_007314.4; = p.A1010T on NM_005158.5) | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.047); catalogued as rs759615562, COSV61017805; called by muse, mutect2, varscan2
- ABL2 | c.2277G>T p.K759N (on ENST00000502732 / NM_007314.4; = p.K744N on NM_005158.5) | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.907); catalogued as COSV61013328; called by muse, mutect2, varscan2
- ABLIM1 | c.217C>T p.R73C | Missense Mutation (SNP) | VAF 54/188 reads (29%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.118); catalogued as rs753417432, COSV53310895; called by muse, mutect2, varscan2
- ABLIM3 | c.1345C>T p.R449W | Missense Mutation (SNP) | VAF 31/118 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as rs139404389; called by muse, mutect2, varscan2
- AC013489.1 | c.1573T>G p.F525V | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT tolerated (0.5); PolyPhen benign (0.062); catalogued as COSV51552552; called by muse, mutect2, varscan2
- AC013489.1 | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.374); catalogued as COSV51552565; called by muse, mutect2, varscan2
- AC023055.1 | c.1131A>C p.E377D | Missense Mutation (SNP) | VAF 41/127 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.984); catalogued as COSV60243826; called by muse, mutect2, varscan2
- AC090517.4 | c.1749G>T p.K583N | Missense Mutation (SNP) | VAF 64/183 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV50996278; called by muse, mutect2, varscan2
- AC090517.4 | c.766A>C p.N256H | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.89); catalogued as COSV50998726; called by muse, mutect2, varscan2
- AC092143.1 | c.1385C>T p.S462L | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV59248071; called by muse, mutect2, varscan2
- AC092718.8 | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as rs932937369, COSV59601556; called by muse, mutect2, varscan2
- AC100868.1 | c.1999C>A p.L667I | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.813); catalogued as COSV99225982; called by muse, mutect2
- AC100868.1 | c.1997A>G p.D666G | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.001); catalogued as COSV99225987; called by muse, mutect2
- AC100868.1 | c.1658A>G p.D553G | Missense Mutation (SNP) | VAF 66/216 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as COSV51846618; called by muse, mutect2, varscan2
- AC100868.1 | c.1256T>G p.L419R | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.18); catalogued as COSV51846633; called by muse, mutect2, varscan2
- AC127029.3 | c.889C>T p.R297C | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV60110507; called by muse, mutect2, varscan2
- ACACA | c.6772C>T p.R2258C | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761713389; called by muse, mutect2, varscan2
- ACACB | c.868G>A p.E290K | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756987109, COSV58138184; called by muse, mutect2, varscan2
- ACACB | c.1279G>A p.D427N | Missense Mutation (SNP) | VAF 16/188 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.297); catalogued as COSV100622832; called by muse, mutect2
- ACACB | c.4619T>A p.F1540Y | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.973); catalogued as COSV100622833; called by muse, mutect2
- ACACB | c.6097G>A p.E2033K | Missense Mutation (SNP) | VAF 111/363 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.391); catalogued as COSV58140308; called by muse, mutect2, varscan2
- ACAD11 | c.921C>A p.F307L | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs768617080, COSV53899123; called by muse, varscan2
- ACAN | c.2792C>T p.T931I | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.974); catalogued as rs1374551151, COSV61364957; called by mutect2, varscan2
- ACAN | c.4439C>A p.S1480Y | Missense Mutation (SNP) | VAF 48/151 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV61364972; called by muse, mutect2, varscan2
- ACAP2 | c.1454A>C p.K485T | Missense Mutation (SNP) | VAF 62/188 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.568); catalogued as COSV58753879; called by muse, mutect2, varscan2
- ACAP2 | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 42/115 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.107); catalogued as COSV58753631; called by muse, mutect2, varscan2
- ACBD6 | c.298A>G p.K100E | Missense Mutation (SNP) | VAF 34/121 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV62574984; called by muse, mutect2, varscan2
- ACBD7 | c.131C>T p.A44V | Missense Mutation (SNP) | VAF 38/120 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.219); catalogued as rs774032600, COSV62252698; called by muse, mutect2, varscan2
- ACCSL | c.878T>C p.V293A | Missense Mutation (SNP) | VAF 48/110 reads (44%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV66581971; called by muse, mutect2, varscan2
- ACCSL | c.1367G>A p.R456Q | Missense Mutation (SNP) | VAF 37/136 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as rs772094369, COSV66581979; called by muse, mutect2, varscan2
- ACE | c.1523G>A p.R508Q | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs746397573, COSV52003879; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACE2 | c.1437G>T p.E479D | Missense Mutation (SNP) | VAF 78/264 reads (30%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.542); catalogued as COSV53026224; called by muse, varscan2
- ACE2 | c.917G>T p.R306I | Missense Mutation (SNP) | VAF 124/383 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); catalogued as COSV53026234; called by muse, mutect2, varscan2
- ACE2 | c.582T>G p.N194K | Missense Mutation (SNP) | VAF 175/642 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV53026247; called by muse, mutect2, varscan2
- ACKR2 | c.592G>T p.D198Y | Missense Mutation (SNP) | VAF 33/585 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); catalogued as rs1292086391, COSV99825503; called by muse, mutect2
- ACKR4 | c.82G>T p.E28* | Nonsense Mutation (SNP) | VAF 42/155 reads (27%) | catalogued as COSV51442893; called by muse, varscan2
- ACMSD | c.175C>T p.R59C | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs267598885, COSV51606002, COSV51609903; called by muse, mutect2, varscan2
- ACO1 | c.1892A>G p.D631G | Missense Mutation (SNP) | VAF 49/196 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59382269; called by muse, mutect2, varscan2
- ACOT13 | c.286T>A p.L96I | Missense Mutation (SNP) | VAF 52/173 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57765038; called by muse, mutect2, varscan2
- ACOX2 | c.995A>G p.D332G | Missense Mutation (SNP) | VAF 46/113 reads (41%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV57149953; called by muse, mutect2, varscan2
- ACP2 | c.539C>T p.S180F | Missense Mutation (SNP) | VAF 79/238 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.028); catalogued as COSV57043275; called by muse, mutect2, varscan2
- ACSBG1 | c.456C>T p.L152= | Splice Region (SNP) | VAF 7/18 reads (39%) | catalogued as rs753800326, COSV51908592; called by muse, mutect2, varscan2
- ACSBG2 | c.1126A>G p.T376A | Missense Mutation (SNP) | VAF 50/159 reads (31%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as COSV53122962; called by muse, mutect2, varscan2
- ACSL1 | c.1204C>T p.R402C | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs768759701, COSV55664441; called by muse, mutect2, varscan2
- ACSL4 | c.1558G>A p.V520I (on ENST00000340800 / NM_022977.2; = p.V479I on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 148/502 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as rs1373567543, COSV61613643; called by muse, mutect2, varscan2
- ACSL4 | c.745T>G p.S249A (on ENST00000340800 / NM_022977.2; = p.S208A on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 66/253 reads (26%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV61615204; called by muse, mutect2, varscan2
- ACSL5 | c.1212G>T p.K404N (on ENST00000354273; = p.K460N on NM_016234.3) | Missense Mutation (SNP) | VAF 61/156 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as COSV61132233; called by muse, mutect2, varscan2
- ACSM2B | c.585G>T p.K195N | Missense Mutation (SNP) | VAF 76/631 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.058); catalogued as COSV61656870, COSV61658390; called by muse, mutect2, varscan2
- ACSM3 | c.228G>T p.K76N | Missense Mutation (SNP) | VAF 54/211 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.239); catalogued as COSV55502696; called by muse, mutect2, varscan2
- ACSM3 | c.1460G>A p.R487Q | Missense Mutation (SNP) | VAF 70/214 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); catalogued as rs1267372126, COSV55500169, COSV55502645; called by muse, mutect2, varscan2
- ACSM4 | c.169G>T p.D57Y | Missense Mutation (SNP) | VAF 16/317 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV101257129; called by muse, mutect2
- ACSM4 | c.473G>A p.R158Q | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs779006926, COSV101257074, COSV68068571; called by muse, mutect2, varscan2
- ACSS1 | c.1936C>T p.R646W | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371113008; called by muse, mutect2, varscan2
- ACSS3 | c.260A>G p.Y87C | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.732); catalogued as COSV54096226; called by muse, mutect2, varscan2
- ACTA1 | c.962C>T p.A321V | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.019); catalogued as COSV64203743; called by muse, mutect2, varscan2
- ACTBL2 | c.871C>T p.R291C | Missense Mutation (SNP) | VAF 35/116 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as rs888995937, COSV70661511; called by muse, varscan2
- ACTBL2 | c.532C>T p.R178C | Missense Mutation (SNP) | VAF 40/112 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.385); catalogued as rs747561123, COSV70661337; called by muse, varscan2
- ACTC1 | c.875G>A p.R292H | Missense Mutation (SNP) | VAF 59/177 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.996); catalogued as COSV51757594; called by muse, mutect2, varscan2
- ACTC1 | c.646G>T p.E216* | Nonsense Mutation (SNP) | VAF 28/98 reads (29%) | catalogued as rs1060499837, COSV51760201; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACTC1 | c.360G>T p.K120N | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.925); catalogued as COSV51760211; called by muse, mutect2, varscan2
- ACTL7B | c.768G>T p.K256N | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.376); catalogued as rs1260635143, COSV65927750; called by muse, mutect2, varscan2
- ACTN1 | c.589C>T p.R197W | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs904887313, COSV51994919; called by muse, mutect2, varscan2
- ACTN2 | c.821C>T p.A274V | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.068); catalogued as COSV63972137, COSV63976838; called by muse, mutect2, varscan2
- ACTR3 | c.721G>T p.E241* | Nonsense Mutation (SNP) | VAF 28/80 reads (35%) | catalogued as COSV54302653; called by muse, mutect2, varscan2
- ACTRT2 | c.736G>A p.D246N | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.304); catalogued as rs761400271, COSV65759846, COSV65760527; called by muse, mutect2, varscan2
- ACTRT2 | c.883C>A p.L295I | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as COSV65759882; called by muse, mutect2, varscan2
- ACVR2A | c.862G>T p.E288* | Nonsense Mutation (SNP) | VAF 23/100 reads (23%) | catalogued as COSV54020876; called by muse, mutect2, varscan2
- ACVR2B | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 49/162 reads (30%) | SIFT tolerated (0.44); PolyPhen benign (0.009); catalogued as rs770339569, COSV61701613; called by muse, mutect2, varscan2
- ADAD1 | c.32C>T p.S11L | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as rs770989160, COSV56641414; called by muse, mutect2, varscan2
- ADAD1 | c.512G>A p.R171Q | Missense Mutation (SNP) | VAF 39/147 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs78087673, COSV99635305; called by muse, mutect2, varscan2
- ADAD1 | c.965T>C p.I322T | Missense Mutation (SNP) | VAF 39/151 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.486); catalogued as rs1295841743, COSV56642187; called by muse, mutect2, varscan2
- ADAL | c.81G>T p.L27F | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67500919; called by muse, varscan2
- ADAM12 | c.1626A>T p.K542N | Missense Mutation (SNP) | VAF 70/212 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV64104538, COSV64110460; called by muse, mutect2, varscan2
- ADAM17 | c.1952G>A p.R651Q | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.777); catalogued as COSV60397996, COSV60398180; called by muse, mutect2, varscan2
- ADAM17 | c.488G>T p.R163I | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.611); catalogued as COSV60400554; called by muse, mutect2, varscan2
- ADAM19 | c.589C>T p.R197* | Nonsense Mutation (SNP) | VAF 49/167 reads (29%) | catalogued as rs199516624, COSV57434609; called by muse, mutect2, varscan2
- ADAM22 | c.307G>A p.D103N | Missense Mutation (SNP) | VAF 50/128 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); catalogued as rs374141909, COSV55983486; called by muse, mutect2, varscan2
- ADAM22 | c.673C>T p.R225W | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs186904476; called by muse, mutect2, varscan2
- ADAM23 | c.347G>T p.R116I | Missense Mutation (SNP) | VAF 37/110 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52222085; called by muse, mutect2, varscan2
- ADAM29 | c.1611A>T p.K537N | Missense Mutation (SNP) | VAF 89/300 reads (30%) | SIFT tolerated (0.54); PolyPhen benign (0.028); catalogued as COSV63665750, COSV63665771; called by muse, varscan2
- ADAM29 | c.1819G>T p.D607Y | Missense Mutation (SNP) | VAF 125/431 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.758); catalogued as COSV63665781, COSV63666862; called by muse, varscan2
- ADAM7 | c.28A>G p.I10V | Missense Mutation (SNP) | VAF 158/516 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.024); catalogued as COSV51543339; called by muse, mutect2, varscan2
- ADAM7 | c.1479G>T p.K493N | Missense Mutation (SNP) | VAF 15/166 reads (9%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.864); catalogued as COSV99443829; called by muse, mutect2, varscan2
- ADAM7 | c.1621A>C p.N541H | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.58); catalogued as COSV51540992; called by muse, mutect2, varscan2
- ADAM9 | c.767G>A p.R256Q | Missense Mutation (SNP) | VAF 60/178 reads (34%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.506); catalogued as rs1344174952, COSV65946589; called by muse, mutect2, varscan2
- ADAM9 | c.1814T>C p.F605S | Missense Mutation (SNP) | VAF 37/137 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65961271; called by muse, mutect2, varscan2
- ADAMTS12 | c.1006C>T p.P336S | Missense Mutation (SNP) | VAF 45/153 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61255281, COSV61270239; called by muse, mutect2, varscan2
- ADAMTS13 | c.2485G>A p.E829K | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.41); PolyPhen benign (0.053); catalogued as rs782110632, COSV100747065; called by muse, mutect2, varscan2
- ADAMTS15 | c.458G>T p.G153V | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.652); catalogued as COSV54507874; called by muse, mutect2, varscan2
- ADAMTS16 | c.1872C>A p.F624L | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV56983992, COSV56998419; called by muse, mutect2, varscan2
- ADAMTS18 | c.3086G>A p.S1029N | Missense Mutation (SNP) | VAF 45/137 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.021); catalogued as rs781753083, COSV51419538; called by muse, mutect2, varscan2
- ADAMTS2 | c.3425T>A p.V1142D | Missense Mutation (SNP) | VAF 55/176 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.024); catalogued as rs780794316, COSV52383795; called by muse, mutect2, varscan2
- ADAMTS20 | c.2207T>C p.V736A | Missense Mutation (SNP) | VAF 41/157 reads (26%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.452); catalogued as COSV67135234; called by muse, mutect2, varscan2
- ADAMTS3 | c.2690G>A p.R897Q | Missense Mutation (SNP) | VAF 71/224 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as rs1213099396, COSV54396785; called by muse, varscan2
- ADAMTS6 | c.2262G>T p.K754N | Missense Mutation (SNP) | VAF 45/146 reads (31%) | SIFT tolerated (0.53); PolyPhen benign (0.433); catalogued as COSV66862194; called by muse, mutect2, varscan2
- ADAMTS6 | c.1553G>A p.R518H | Missense Mutation (SNP) | VAF 45/162 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as rs1442947114, COSV66862199; called by muse, mutect2, varscan2
- ADAMTSL1 | c.226T>C p.C76R | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs764550974, COSV52820053; called by muse, mutect2, varscan2
- ADAMTSL1 | c.962C>T p.S321L | Missense Mutation (SNP) | VAF 47/141 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs777583332, COSV52813087; called by muse, mutect2, varscan2
- ADCY1 | c.2771G>T p.S924I | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52038651; called by muse, mutect2, varscan2
- ADCY10 | c.2815G>A p.E939K | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs746591110, COSV63241530; called by muse, mutect2, varscan2
- ADCY2 | c.1733G>T p.R578I | Missense Mutation (SNP) | VAF 40/120 reads (33%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.658); catalogued as rs1296273812, COSV57885632; called by muse, mutect2, varscan2
- ADCY2 | c.1848T>G p.I616M | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.27); catalogued as rs1294791275, COSV57885647; called by muse, mutect2, varscan2
- ADCY5 | c.1988G>T p.R663I | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV59200898; called by muse, mutect2, varscan2
- ADCY8 | c.3119A>G p.Y1040C | Missense Mutation (SNP) | VAF 22/180 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53917273; called by muse, mutect2, varscan2
- ADCY8 | c.1541C>T p.S514L | Missense Mutation (SNP) | VAF 74/242 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763633456, COSV53917295; called by muse, varscan2
- ADCY9 | c.2958C>A p.F986L | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV53578537; called by muse, mutect2, varscan2
- ADCY9 | c.980A>C p.K327T | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); catalogued as COSV53578550; called by muse, mutect2, varscan2
- ADCYAP1 | c.434G>A p.R145Q | Missense Mutation (SNP) | VAF 35/143 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.977); catalogued as rs1318104167, COSV52485903; called by muse, varscan2
- ADCYAP1 | c.515G>A p.R172Q | Missense Mutation (SNP) | VAF 38/115 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV52486014, COSV52486041; called by muse, varscan2
- ADCYAP1R1 | c.962T>G p.F321C | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58445180; called by muse, mutect2, varscan2
- ADD3 | c.479A>T p.Y160F | Missense Mutation (SNP) | VAF 52/195 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV53324127, COSV99523469; called by muse, mutect2, varscan2
- ADD3 | c.880C>A p.H294N | Missense Mutation (SNP) | VAF 55/358 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV53324149; called by muse, mutect2, varscan2
- ADD3 | c.1708G>A p.E570K | Missense Mutation (SNP) | VAF 69/215 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.436); catalogued as rs767558945, COSV53321083; called by muse, mutect2, varscan2
- ADGRA3 | c.3488G>A p.R1163Q | Missense Mutation (SNP) | VAF 40/146 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.75); catalogued as rs771076973, COSV51565862; called by muse, varscan2
- ADGRA3 | c.2905G>A p.E969K | Missense Mutation (SNP) | VAF 80/299 reads (27%) | SIFT tolerated (0.84); PolyPhen possibly damaging (0.535); catalogued as rs746516223, COSV51562557; called by muse, mutect2, varscan2
- ADGRA3 | c.1873G>T p.E625* | Nonsense Mutation (SNP) | VAF 27/107 reads (25%) | catalogued as COSV51565883; called by muse, mutect2, varscan2
- ADGRB3 | c.374A>C p.K125T | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV65407405; called by muse, mutect2, varscan2
- ADGRB3 | c.470T>C p.V157A | Missense Mutation (SNP) | VAF 39/114 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV65407408; called by muse, mutect2, varscan2
- ADGRB3 | c.869-1G>T p.X290_splice | Splice Site (SNP) | VAF 6/19 reads (32%) | catalogued as COSV65407411; called by muse, mutect2, varscan2
- ADGRB3 | c.1373G>T p.W458L | Missense Mutation (SNP) | VAF 67/206 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65407416; called by muse, mutect2, varscan2
- ADGRB3 | c.1534G>T p.E512* | Nonsense Mutation (SNP) | VAF 26/90 reads (29%) | catalogued as COSV65407422; called by muse, varscan2
- ADGRB3 | c.1577G>T p.R526I | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.939); catalogued as rs968821820, COSV65407425; called by muse, varscan2
- ADGRB3 | c.1736T>A p.I579N | Missense Mutation (SNP) | VAF 133/559 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.459); catalogued as COSV65403186, COSV65407430; called by muse, mutect2, varscan2
- ADGRB3 | c.2118T>G p.I706M | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.5); catalogued as COSV65407435; called by muse, mutect2, varscan2
- ADGRB3 | c.2402C>T p.S801L | Missense Mutation (SNP) | VAF 39/132 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.102); catalogued as rs747907463, COSV101000565, COSV65385017; called by muse, mutect2, varscan2
- ADGRB3 | c.2741T>G p.L914R | Missense Mutation (SNP) | VAF 42/166 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53253084; called by muse, varscan2
- ADGRB3 | c.3064C>A p.L1022I | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53253093; called by muse, mutect2, varscan2
- ADGRB3 | c.3527C>T p.S1176L | Missense Mutation (SNP) | VAF 58/196 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.196); catalogued as rs142863825, COSV53234039; called by muse, mutect2, varscan2
- ADGRE5 | c.2302A>G p.T768A (on ENST00000242786 / NM_078481.4; = p.T675A on NM_001784.5) | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54392537; called by muse, mutect2, varscan2
- ADGRF4 | c.392T>C p.V131A | Missense Mutation (SNP) | VAF 56/152 reads (37%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV51954925; called by muse, mutect2, varscan2
- ADGRF5 | c.4028C>T p.S1343L | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs780829581, COSV99345538; called by mutect2, varscan2
- ADGRF5 | c.466G>T p.E156* | Nonsense Mutation (SNP) | VAF 58/210 reads (28%) | catalogued as COSV51937265; called by muse, mutect2, varscan2
- ADGRG2 | c.526T>C p.C176R (on ENST00000379869 / NM_001079858.3; = p.C173R on NM_005756.4) | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100492227; called by muse, mutect2, varscan2
- ADGRG3 | c.118G>A p.D40N | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as rs368017305; called by muse, mutect2, varscan2
- ADGRG4 | c.1742G>A p.R581H | Missense Mutation (SNP) | VAF 219/707 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs760044574, COSV54954779, COSV54961950; called by muse, mutect2, varscan2
- ADGRG4 | c.3848C>A p.S1283Y | Missense Mutation (SNP) | VAF 194/613 reads (32%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs377239456, COSV54957590, COSV54966049; called by muse, mutect2, varscan2
- ADGRG4 | c.6698C>T p.S2233L | Missense Mutation (SNP) | VAF 54/150 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs567340291, COSV54952396; called by muse, mutect2, varscan2
- ADGRG7 | c.964G>A p.G322S | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs376592781; called by muse, mutect2, varscan2
- ADGRG7 | c.1968G>T p.Q656H | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.065); catalogued as rs764538012, COSV56299025; called by muse, mutect2, varscan2
- ADGRL3 | c.3620G>A p.R1207Q (on ENST00000506720 / NM_001322402.2; = p.R1139Q on NM_015236.6) | Missense Mutation (SNP) | VAF 35/140 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs372464266, COSV72229973; called by muse, mutect2, varscan2
- ADGRL4 | c.1078C>T p.R360* | Nonsense Mutation (SNP) | VAF 35/116 reads (30%) | catalogued as rs767685899, COSV66060741; called by muse, mutect2, varscan2
- ADGRL4 | c.412G>T p.E138* | Nonsense Mutation (SNP) | VAF 22/61 reads (36%) | catalogued as COSV66063279; called by muse, mutect2, varscan2
- ADGRL4 | c.341A>G p.N114S | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.007); catalogued as COSV66063282; called by muse, mutect2, varscan2
- ADGRV1 | c.7619T>G p.I2540S | Missense Mutation (SNP) | VAF 69/214 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV67990466; called by muse, mutect2, varscan2
- ADGRV1 | c.11539G>T p.E3847* | Nonsense Mutation (SNP) | VAF 24/104 reads (23%) | catalogued as COSV67990470; called by muse, mutect2, varscan2
- ADGRV1 | c.12668C>A p.A4223D | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV101315868; called by muse, mutect2
- ADGRV1 | c.13994T>G p.L4665R | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.53); PolyPhen benign (0.01); catalogued as COSV67990473; called by muse, mutect2, varscan2
- ADGRV1 | c.17851A>G p.T5951A | Missense Mutation (SNP) | VAF 8/109 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.214); catalogued as COSV101315870; called by muse, mutect2
- ADH1B | c.1062A>C p.E354D | Missense Mutation (SNP) | VAF 15/129 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.025); catalogued as COSV59297586; called by muse, mutect2, varscan2
- ADIPOR1 | c.605G>A p.R202Q | Missense Mutation (SNP) | VAF 12/214 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.025); catalogued as COSV100579505; called by muse, mutect2
- ADIPOR2 | c.92G>A p.R31Q | Missense Mutation (SNP) | VAF 44/168 reads (26%) | SIFT tolerated (0.54); PolyPhen benign (0.023); catalogued as rs200483941, COSV63946468; called by muse, mutect2, varscan2
- ADIPOR2 | c.433G>T p.E145* | Nonsense Mutation (SNP) | VAF 52/133 reads (39%) | catalogued as COSV63947166, COSV63947748; called by muse, mutect2, varscan2
- ADORA3 | c.613C>T p.R205W | Missense Mutation (SNP) | VAF 90/304 reads (30%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as rs557748857, COSV53985808; called by muse, mutect2, varscan2
- ADRA1A | c.397C>T p.R133C | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs968763557, COSV52369597; called by muse, mutect2, varscan2
- AF196969.1 | c.307G>T p.E103* | Nonsense Mutation (SNP) | VAF 61/620 reads (10%) | catalogued as CM085372, COSV52142007; called by muse, varscan2
- AFDN | c.3465G>T p.K1155N | Missense Mutation (SNP) | VAF 63/242 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.132); catalogued as COSV60050046, COSV60051636; called by muse, varscan2
- AFDN | c.4947+3T>G | Splice Region (SNP) | VAF 52/164 reads (32%) | catalogued as COSV60050070; called by muse, varscan2
- AFF2 | c.98G>T p.R33M | Missense Mutation (SNP) | VAF 56/416 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV60673463; called by muse, mutect2, varscan2
- AFG3L2 | c.418G>A p.D140N | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.019); catalogued as rs758108965, COSV52315244; called by muse, mutect2, varscan2
- AFM | c.1050C>A p.F350L | Missense Mutation (SNP) | VAF 40/137 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.066); catalogued as rs1445434562, COSV56921185; called by muse, varscan2
- AFP | c.1593C>A p.F531L | Missense Mutation (SNP) | VAF 44/117 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56926148, COSV56927158; called by muse, mutect2, varscan2
- AGAP1 | c.505A>G p.S169G | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV58333202; called by muse, mutect2, varscan2
- AGAP6 | c.1847T>C p.L616P (on ENST00000374056 / NM_001365867.1; = p.L639P on NM_001077665.2) | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV65018031; called by mutect2, varscan2
- AGBL2 | c.1474A>G p.I492V | Missense Mutation (SNP) | VAF 97/329 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as COSV54093910; called by muse, mutect2, varscan2
- AGBL5 | c.275T>G p.I92S | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); catalogued as COSV59937313; called by muse, mutect2, varscan2
- AGBL5 | c.1195C>T p.L399F | Missense Mutation (SNP) | VAF 50/162 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.022); catalogued as COSV59937323; called by muse, mutect2, varscan2
- AGGF1 | c.92A>C p.K31T | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV57230297; called by muse, mutect2
- AGGF1 | c.1401A>C p.Q467H | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57230303; called by muse, mutect2, varscan2
- AGK | c.707A>C p.H236P | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.195); catalogued as COSV100814615; called by muse, mutect2
- AGL | c.1327G>T p.E443* | Nonsense Mutation (SNP) | VAF 11/45 reads (24%) | catalogued as rs1461705551, COSV54055693; called by muse, mutect2, varscan2
- AGMAT | c.608C>T p.A203V | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.029); catalogued as rs772811886, COSV65436065; called by muse, mutect2, varscan2
- AGMO | c.248G>A p.R83Q | Missense Mutation (SNP) | VAF 42/164 reads (26%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs373631505; called by muse, mutect2, varscan2
- AGO4 | c.1021C>T p.R341* | Nonsense Mutation (SNP) | VAF 42/152 reads (28%) | catalogued as COSV64617889; called by muse, mutect2, varscan2
- AGPAT4 | c.503A>C p.K168T | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0.084); catalogued as COSV57248410; called by muse, mutect2, varscan2
- AGPS | c.790-1G>A p.X264_splice | Splice Site (SNP) | VAF 34/127 reads (27%) | catalogued as COSV51566223, COSV51568590; called by muse, varscan2
- AGPS | c.1126G>T p.E376* | Nonsense Mutation (SNP) | VAF 42/141 reads (30%) | catalogued as COSV51566645; called by muse, mutect2, varscan2
- AGTR2 | c.835G>A p.D279N | Missense Mutation (SNP) | VAF 67/197 reads (34%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.737); catalogued as COSV64156745; called by muse, mutect2, varscan2
- AGXT | c.638C>T p.A213V | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.932); catalogued as rs569680503, COSV56755043; called by muse, mutect2, varscan2
- AGXT2 | c.1066T>G p.F356V | Missense Mutation (SNP) | VAF 131/421 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.693); catalogued as COSV51488456; called by muse, mutect2, varscan2
- AHCYL2 | c.445T>C p.S149P | Missense Mutation (SNP) | VAF 36/121 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV61489451; called by muse, mutect2, varscan2
- AHNAK | c.10691C>A p.S3564Y | Missense Mutation (SNP) | VAF 111/324 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV57222173; called by muse, mutect2, varscan2
- AHNAK | c.7704G>T p.K2568N | Missense Mutation (SNP) | VAF 98/348 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV57222188; called by muse, mutect2, varscan2
- AHNAK | c.4956G>T p.K1652N | Missense Mutation (SNP) | VAF 55/381 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV57222203; called by muse, mutect2, varscan2
- AHNAK2 | c.16082G>A p.S5361N | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.5); PolyPhen benign (0.287); catalogued as COSV60922336; called by muse, mutect2, varscan2
- AHNAK2 | c.15700G>T p.E5234* | Nonsense Mutation (SNP) | VAF 31/121 reads (26%) | catalogued as COSV60913634, COSV60922350; called by muse, mutect2, varscan2
- AHNAK2 | c.12322G>A p.A4108T | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.794); catalogued as rs760896585, COSV60922361; called by muse, mutect2, varscan2
- AHNAK2 | c.4963G>T p.D1655Y | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60922373; called by muse, mutect2, varscan2
- AHNAK2 | c.1983A>C p.Q661H | Missense Mutation (SNP) | VAF 40/139 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.26); catalogued as COSV60922379; called by muse, mutect2, varscan2
- AHNAK2 | c.1470G>T p.K490N | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV60922388; called by muse, mutect2, varscan2
- AHNAK2 | c.532C>A p.L178I | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60922397; called by muse, mutect2, varscan2
- AHR | c.734A>G p.Y245C | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.447); catalogued as COSV54124856; called by muse, mutect2, varscan2
- AIDA | c.851G>T p.R284I | Missense Mutation (SNP) | VAF 30/162 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV60514769; called by muse, mutect2, varscan2
- AIFM1 | c.340G>A p.A114T | Missense Mutation (SNP) | VAF 37/148 reads (25%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs772308346, COSV54856478; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- AIM2 | c.599A>C p.K200T | Missense Mutation (SNP) | VAF 25/188 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV63700832; called by muse, mutect2, varscan2
- AIM2 | c.525G>T p.E175D | Missense Mutation (SNP) | VAF 69/207 reads (33%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.538); catalogued as COSV63700835; called by muse, mutect2, varscan2
- AIMP1 | c.146G>A p.R49Q | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs747675209, COSV63639130; called by muse, mutect2, varscan2
- AK4 | c.404T>C p.V135A | Missense Mutation (SNP) | VAF 36/127 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59198547; called by muse, mutect2, varscan2
- AK4 | c.616G>A p.V206I | Missense Mutation (SNP) | VAF 44/141 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs149373720, COSV59198556; called by muse, mutect2, varscan2
- AK7 | c.458C>T p.S153L | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774815872, COSV50876171; called by muse, mutect2, varscan2
- AKAP10 | c.1791C>A p.F597L | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); catalogued as COSV56732209, COSV56732736; called by muse, mutect2, varscan2
- AKAP10 | c.128C>T p.S43F | Missense Mutation (SNP) | VAF 36/137 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.046); catalogued as COSV56732219; called by muse, mutect2, varscan2
- AKAP11 | c.4286G>T p.R1429I | Missense Mutation (SNP) | VAF 61/182 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs1308479533, COSV50293081; called by muse, mutect2, varscan2
- AKAP11 | c.5131G>T p.E1711* | Nonsense Mutation (SNP) | VAF 55/180 reads (31%) | catalogued as COSV50298855; called by muse, mutect2, varscan2
- AKAP12 | c.1553A>C p.K518T | Missense Mutation (SNP) | VAF 87/303 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53578671; called by muse, mutect2, varscan2
- AKAP13 | c.2228G>A p.R743Q | Missense Mutation (SNP) | VAF 68/256 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.015); catalogued as rs769554632, COSV63464576; called by muse, mutect2, varscan2
- AKAP4 | c.1823G>T p.G608V | Missense Mutation (SNP) | VAF 30/442 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.983); catalogued as COSV100654253; called by muse, mutect2
- AKAP4 | c.791G>A p.R264Q | Missense Mutation (SNP) | VAF 74/269 reads (28%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.817); catalogued as rs782377975, COSV62074933; called by muse, mutect2, varscan2
- AKAP4 | c.674C>T p.S225F | Missense Mutation (SNP) | VAF 117/445 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.799); catalogued as COSV62074936; called by muse, mutect2, varscan2
- AKAP6 | c.6416T>C p.L2139P | Missense Mutation (SNP) | VAF 62/191 reads (32%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as COSV55222904; called by muse, mutect2, varscan2
- AKAP7 | c.182G>T p.R61I | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.125); catalogued as COSV63505492; called by muse, mutect2, varscan2
- AKAP7 | c.591G>T p.E197D | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.026); catalogued as COSV53836330; called by muse, mutect2, varscan2
- AKAP9 | c.3065G>T p.G1022V | Missense Mutation (SNP) | VAF 54/198 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.584); catalogued as COSV100663031, COSV62352298; called by muse, mutect2, varscan2
- AKAP9 | c.10499G>A p.R3500K (on ENST00000359028; = p.R3476K on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 60/229 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770926523, COSV62342275, COSV62352310; called by muse, mutect2, varscan2
- AKNAD1 | c.2431G>T p.E811* | Nonsense Mutation (SNP) | VAF 34/239 reads (14%) | catalogued as COSV64172137; called by muse, varscan2
- AKR1C4 | c.928T>G p.F310V | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV54124319; called by muse, mutect2, varscan2
- AKR1D1 | c.880G>T p.E294* | Nonsense Mutation (SNP) | VAF 15/53 reads (28%) | catalogued as COSV54338891, COSV54339447; called by muse, mutect2, varscan2
- AKR1E2 | c.261T>G p.S87R | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as COSV53631034; called by muse, varscan2
- AKT2 | c.206G>A p.R69Q | Missense Mutation (SNP) | VAF 34/190 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.149); catalogued as rs1485745630, COSV60909229, COSV60909859; called by muse, mutect2, varscan2
- AL592490.1 | c.712G>T p.D238Y | Missense Mutation (SNP) | VAF 64/182 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69427022; called by muse, mutect2, varscan2
- AL645922.1 | c.1357G>T p.E453* | Nonsense Mutation (SNP) | VAF 21/78 reads (27%) | catalogued as COSV54961604; called by muse, mutect2, varscan2
- AL713999.2 | c.488G>T p.R163I | Missense Mutation (SNP) | VAF 27/156 reads (17%) | catalogued as COSV55279662, COSV99826072; called by muse, mutect2, varscan2
- ALAS2 | c.1486A>G p.K496E | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT tolerated (0.54); PolyPhen benign (0.05); catalogued as COSV58192070; called by muse, mutect2, varscan2
- ALB | c.590A>G p.D197G | Missense Mutation (SNP) | VAF 64/203 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.557); catalogued as rs1335184195, COSV55740269; called by muse, mutect2, varscan2
- ALDH1A1 | c.452T>G p.F151C | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as COSV52792847; called by muse, mutect2, varscan2
- ALDH1A2 | c.1427C>T p.A476V | Missense Mutation (SNP) | VAF 44/167 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV51085906; called by muse, mutect2, varscan2
- ALDH1A2 | c.1378G>T p.V460L | Missense Mutation (SNP) | VAF 31/124 reads (25%) | SIFT tolerated (0.87); PolyPhen benign (0.006); catalogued as COSV51085940; called by muse, mutect2, varscan2
- ALDH1A2 | c.442C>T p.R148* | Nonsense Mutation (SNP) | VAF 20/72 reads (28%) | catalogued as COSV51078163; called by muse, mutect2, varscan2
- ALDH1A3 | c.377T>G p.F126C | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV60902549; called by muse, mutect2, varscan2
- ALDH1A3 | c.1342C>A p.L448I | Missense Mutation (SNP) | VAF 49/188 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV60902555; called by muse, mutect2, varscan2
- ALDH1B1 | c.770A>G p.K257R | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV66620235; called by muse, mutect2, varscan2
- ALDH5A1 | c.1169A>G p.E390G | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.925); catalogued as rs142677472; ClinVar: uncertain significance; called by muse, varscan2
- ALDH6A1 | c.418C>T p.R140* | Nonsense Mutation (SNP) | VAF 49/174 reads (28%) | catalogued as rs201935817, COSV63246832; called by muse, mutect2, varscan2
- ALDH8A1 | c.1344G>A p.W448* | Nonsense Mutation (SNP) | VAF 20/73 reads (27%) | catalogued as COSV55642989; called by muse, mutect2, varscan2
- ALDOB | c.11G>A p.R4Q | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs767812270, COSV66398262; called by muse, mutect2, varscan2
- ALDOC | c.776G>A p.R259H | Missense Mutation (SNP) | VAF 41/110 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.415); catalogued as rs765845189, COSV52024310; called by muse, mutect2, varscan2
- ALG11 | c.773C>A p.S258Y | Missense Mutation (SNP) | VAF 44/142 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV73000743, COSV73000752; called by muse, mutect2, varscan2
- ALG11 | c.1130C>A p.P377Q | Missense Mutation (SNP) | VAF 58/167 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV73000744; called by muse, mutect2, varscan2
- ALG13 | c.743C>T p.S248L | Missense Mutation (SNP) | VAF 163/458 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV52642134; called by muse, mutect2, varscan2
- ALG13 | c.1165C>T p.R389* | Nonsense Mutation (SNP) | VAF 7/13 reads (54%) | catalogued as COSV52638289; called by muse, mutect2, varscan2
- ALG13 | c.3346A>C p.N1116H | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.87); catalogued as COSV52642167; called by muse, mutect2, varscan2
- ALG5 | c.925C>T p.R309* | Nonsense Mutation (SNP) | VAF 27/88 reads (31%) | catalogued as COSV53504958; called by muse, mutect2, varscan2
- ALG6 | c.1099A>G p.T367A | Missense Mutation (SNP) | VAF 35/167 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.043); catalogued as rs1314773247, COSV54766304; called by muse, mutect2, varscan2
- ALMS1 | c.481G>T p.E161* | Nonsense Mutation (SNP) | VAF 63/212 reads (30%) | catalogued as rs754374314, COSV52515737; called by muse, mutect2, varscan2
- ALMS1 | c.875G>A p.R292H | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.027); catalogued as rs966793166, COSV100042682, COSV52506747; called by muse, mutect2, varscan2
- ALMS1 | c.2287T>G p.S763A | Missense Mutation (SNP) | VAF 152/504 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.508); catalogued as COSV52515760; called by muse, mutect2, varscan2
- ALMS1 | c.3339G>T p.E1113D | Missense Mutation (SNP) | VAF 136/418 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52515771; called by muse, mutect2, varscan2
- ALMS1 | c.6783A>C p.E2261D | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV52515783; called by muse, mutect2, varscan2
- ALMS1 | c.10193C>A p.S3398Y | Missense Mutation (SNP) | VAF 73/264 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV52515794; called by muse, mutect2, varscan2
- ALOX15B | c.1314C>A p.F438L | Missense Mutation (SNP) | VAF 39/121 reads (32%) | SIFT tolerated (0.85); PolyPhen benign (0.015); catalogued as COSV66479113, COSV66479803; called by muse, mutect2, varscan2
- ALOX5 | c.395G>A p.R132Q | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765467323, COSV65553396; called by muse, mutect2, varscan2
- ALPG | c.129G>T p.K43N | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.3); catalogued as COSV54967216; called by muse, mutect2, varscan2
- ALPK1 | c.896C>T p.A299V | Missense Mutation (SNP) | VAF 66/192 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); catalogued as COSV51592569; called by muse, mutect2
- ALPK3 | c.1808G>T p.R603I | Missense Mutation (SNP) | VAF 41/137 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.276); catalogued as rs1412921795, COSV104386100, COSV51936402; called by muse, mutect2, varscan2
- ALS2 | c.4262G>A p.R1421Q | Missense Mutation (SNP) | VAF 60/210 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.895); catalogued as rs770885030, COSV51888325, COSV51889832; called by muse, mutect2, varscan2
- ALX1 | c.497C>T p.A166V | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57493319; called by muse, mutect2, varscan2
- ALX3 | c.347A>G p.D116G | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); catalogued as rs373683008; called by mutect2, varscan2
- ALX4 | c.1141G>A p.E381K | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.484); catalogued as rs768153687, COSV100241118, COSV61327672; called by muse, mutect2, varscan2
- AMBN | c.674C>A p.S225Y | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.913); catalogued as COSV59825108, COSV59825190, COSV59825299; called by muse, mutect2, varscan2
- AMBN | c.951G>T p.E317D | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.617); catalogued as COSV59827238; called by muse, mutect2, varscan2
- AMBP | c.782A>G p.Y261C | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs900354665, COSV54324698; called by muse, mutect2, varscan2
- AMDHD1 | c.640A>C p.K214Q | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.018); catalogued as COSV57139586; called by muse, mutect2, varscan2
- AMIGO1 | c.463G>A p.D155N | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT tolerated (0.4); PolyPhen benign (0.054); catalogued as COSV63990505; called by muse, mutect2, varscan2
- AMOTL1 | c.2300C>A p.A767D | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58568479; called by muse, mutect2, varscan2
- AMPD1 | c.2152A>G p.N718D | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV62417296; called by muse, mutect2, varscan2
- AMPD1 | c.1801C>A p.L601M | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.513); catalogued as COSV62417301; called by muse, mutect2, varscan2
- AMTN | c.575G>T p.R192M | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV59489556; called by muse, mutect2, varscan2
- AMY2A | c.1150G>T p.E384* | Nonsense Mutation (SNP) | VAF 142/500 reads (28%) | catalogued as rs1185757504, COSV70214228; called by muse, varscan2
- AMY2B | c.614G>T p.G205V | Missense Mutation (SNP) | VAF 135/426 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63716164; called by muse, mutect2, varscan2
- ANAPC1 | c.5355G>T p.E1785D | Missense Mutation (SNP) | VAF 28/107 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.967); catalogued as COSV61977588, COSV61977724; called by muse, mutect2, varscan2
- ANAPC1 | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 28/117 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1415933638, COSV61977740; called by muse, mutect2, varscan2
- ANAPC13 | c.86T>C p.V29A | Missense Mutation (SNP) | VAF 34/168 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV59677671; called by muse, mutect2, varscan2
- ANAPC2 | c.155A>G p.E52G | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as COSV100119040; called by muse, mutect2
- ANGPT2 | c.93G>T p.K31N | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.241); catalogued as COSV57337044; called by muse, mutect2, varscan2
- ANGPTL1 | c.130G>T p.E44* | Nonsense Mutation (SNP) | VAF 72/211 reads (34%) | catalogued as COSV52367273; called by muse, mutect2, varscan2
- ANGPTL3 | c.628G>T p.E210* | Nonsense Mutation (SNP) | VAF 41/145 reads (28%) | catalogued as COSV52013972; called by muse, mutect2, varscan2
- ANGPTL3 | c.1176C>A p.F392L | Missense Mutation (SNP) | VAF 43/148 reads (29%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV52013981; called by muse, mutect2, varscan2
- ANK1 | c.386T>G p.F129C | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.59); catalogued as COSV55887992; called by muse, mutect2, varscan2
- ANK2 | c.4894G>T p.D1632Y | Missense Mutation (SNP) | VAF 97/327 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52175040; called by muse, mutect2, varscan2
- ANK2 | c.6252G>T p.K2084N | Missense Mutation (SNP) | VAF 81/255 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.206); catalogued as COSV52175052, COSV52192822; called by muse, mutect2, varscan2
- ANK2 | c.6820C>T p.R2274C | Missense Mutation (SNP) | VAF 62/191 reads (32%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.001); catalogued as rs140258681; called by muse, varscan2
- ANK2 | c.8953G>T p.E2985* | Nonsense Mutation (SNP) | VAF 57/436 reads (13%) | catalogued as COSV52175078; called by muse, mutect2, varscan2
- ANK2 | c.11349G>T p.E3783D | Missense Mutation (SNP) | VAF 12/224 reads (5%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.014); catalogued as COSV100001471; called by muse, mutect2
- ANK3 | c.12679G>T p.D4227Y (on ENST00000280772 / NM_001320874.2; = p.D851Y on NM_001149.3) | Missense Mutation (SNP) | VAF 56/150 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV55069727; called by muse, mutect2, varscan2
- ANK3 | c.11381C>A p.S3794Y | Missense Mutation (SNP) | VAF 102/363 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.055); catalogued as COSV55054127; called by muse, mutect2, varscan2
- ANK3 | c.4283C>T p.A1428V (on ENST00000280772 / NM_001320874.2; = p.A562V on NM_001149.3) | Missense Mutation (SNP) | VAF 86/322 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.489); catalogued as rs767554170, COSV55069759; called by muse, varscan2
- ANK3 | c.2756C>T p.S919L (on ENST00000280772 / NM_001320874.2; = p.S53L on NM_001149.3) | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs775705277, COSV55053192; called by muse, mutect2, varscan2
- ANK3 | c.556G>A p.D186N | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated (0.58); PolyPhen benign (0.03); catalogued as COSV55069807; called by muse, mutect2, varscan2
- ANKAR | c.344A>G p.N115S | Missense Mutation (SNP) | VAF 13/158 reads (8%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.991); catalogued as COSV99854202; called by muse, mutect2
- ANKHD1-EIF4EBP3 | c.4364A>C p.K1455T | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV51853201; called by muse, mutect2, varscan2
- ANKK1 | c.2047G>A p.A683T | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.14); catalogued as rs778503691, COSV100392904, COSV58273176; called by mutect2, varscan2
- ANKMY1 | c.1849G>A p.D617N | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1250850007, COSV56037683; called by muse, mutect2, varscan2
- ANKMY2 | c.860G>A p.R287Q | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.14); catalogued as rs747549296, COSV61012163; called by muse, mutect2, varscan2
- ANKRD10 | c.634C>T p.R212* | Nonsense Mutation (SNP) | VAF 8/113 reads (7%) | catalogued as COSV57443365; called by muse, mutect2
- ANKRD12 | c.134G>A p.R45Q | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.342); catalogued as rs780114226, COSV50835445; called by muse, mutect2, varscan2
- ANKRD17 | c.5569A>C p.I1857L | Missense Mutation (SNP) | VAF 39/545 reads (7%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as COSV100429155; called by muse, mutect2
- ANKRD17 | c.2218G>A p.D740N | Missense Mutation (SNP) | VAF 43/137 reads (31%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.801); catalogued as rs1476151741, COSV58224235; called by muse, mutect2, varscan2
- ANKRD17 | c.1768G>A p.V590I | Missense Mutation (SNP) | VAF 33/116 reads (28%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.964); catalogued as rs368988558; called by muse, mutect2, varscan2
- ANKRD17 | c.604C>T p.R202W | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.957); catalogued as rs763910615, COSV58221383; called by muse, mutect2, varscan2
- ANKRD20A1 | c.537G>T p.E179D | Missense Mutation (SNP) | VAF 29/229 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.825); catalogued as rs1207178418; called by muse, mutect2, varscan2
- ANKRD20A4P | c.1027G>T p.D343Y | Missense Mutation (SNP) | VAF 35/331 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); catalogued as COSV62006416; called by muse, mutect2, varscan2
- ANKRD22 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 33/112 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.097); catalogued as rs758073859, COSV64236209; called by muse, mutect2
- ANKRD24 | c.958C>T p.R320* | Nonsense Mutation (SNP) | VAF 9/18 reads (50%) | catalogued as rs779286012, COSV53668828; called by muse, mutect2, varscan2
- ANKRD24 | c.1765G>A p.A589T | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0.001); catalogued as rs1295811922, COSV53673130; called by muse, mutect2, varscan2
- ANKRD26 | c.2851G>T p.E951* | Nonsense Mutation (SNP) | VAF 54/154 reads (35%) | catalogued as rs1291484492, COSV65776762; called by muse, mutect2, varscan2
- ANKRD26 | c.239A>G p.N80S | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.02); catalogued as COSV65796593; called by muse, mutect2, varscan2
- ANKRD27 | c.1575G>T p.Q525H | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV100042775; called by muse, mutect2
- ANKRD27 | c.469G>A p.A157T | Missense Mutation (SNP) | VAF 69/202 reads (34%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs568458804, COSV60133721; called by muse, mutect2, varscan2
- ANKRD28 | c.2408C>T p.A803V | Missense Mutation (SNP) | VAF 96/287 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.013); catalogued as COSV67519338; called by muse, mutect2, varscan2
- ANKRD28 | c.73C>T p.R25* | Nonsense Mutation (SNP) | VAF 78/142 reads (55%) | catalogued as COSV67516849; called by muse, mutect2, varscan2
- ANKRD29 | c.26A>C p.E9A | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.525); catalogued as COSV52426860; called by muse, mutect2, varscan2
- ANKRD30A | c.428T>C p.L143P (on ENST00000611781; = p.L87P on NM_052997.2) | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1229754895, COSV64615644; called by muse, mutect2, varscan2
- ANKRD30A | c.1426G>A p.E476K (on ENST00000611781; = p.E420K on NM_052997.2) | Missense Mutation (SNP) | VAF 50/222 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.899); catalogued as rs867286949, COSV64607688; called by muse, varscan2
- ANKRD30A | c.1999G>A p.A667T (on ENST00000611781; = p.A611T on NM_052997.2) | Missense Mutation (SNP) | VAF 64/183 reads (35%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.827); catalogued as rs1275725898, COSV64615653; called by muse, varscan2
- ANKRD33 | c.292C>T p.R98W (on ENST00000340970 / NM_001304459.2; = p.R223W on NM_182608.4) | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs267603510, COSV56605570; called by muse, mutect2, varscan2
- ANKRD35 | c.22T>C p.S8P | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs781847464, COSV62911022; called by muse, mutect2, varscan2
- ANKRD42 | c.685G>T p.D229Y | Missense Mutation (SNP) | VAF 90/271 reads (33%) | SIFT tolerated (0.38); PolyPhen benign (0.009); catalogued as COSV52614851, COSV52615086; called by muse, mutect2, varscan2
- ANKRD44 | c.1220C>T p.T407M | Missense Mutation (SNP) | VAF 71/209 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1384342605, COSV56551241; called by muse, varscan2
- ANKRD45 | c.317A>C p.K106T | Missense Mutation (SNP) | VAF 52/151 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.348); catalogued as COSV60961894; called by muse, mutect2, varscan2
- ANKRD50 | c.2209C>T p.R737* | Nonsense Mutation (SNP) | VAF 53/168 reads (32%) | catalogued as COSV101538877, COSV72385130; called by muse, mutect2, varscan2
- ANKRD55 | c.423-2A>G p.X141_splice | Splice Site (SNP) | VAF 30/104 reads (29%) | catalogued as rs749250034, COSV61948643; called by muse, mutect2, varscan2
- ANKRD6 | c.1533G>T p.Q511H | Missense Mutation (SNP) | VAF 28/107 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.965); catalogued as COSV60233884; called by muse, mutect2, varscan2
- ANKS1A | c.2556G>T p.L852F | Missense Mutation (SNP) | VAF 40/124 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.737); catalogued as COSV64462476; called by muse, mutect2, varscan2
- ANKS1B | c.3743T>G p.F1248C (on ENST00000547776 / NM_152788.4; = p.F414C on NM_020140.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.759); catalogued as COSV59122193; called by muse, mutect2, varscan2
- ANKS1B | c.1568G>A p.R523Q | Missense Mutation (SNP) | VAF 30/125 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as rs757376360, COSV61362600; called by muse, mutect2, varscan2
- ANKS6 | c.1165C>T p.R389C | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762633578, COSV62049898; called by muse, mutect2, varscan2
- ANLN | c.1501A>C p.N501H | Missense Mutation (SNP) | VAF 117/356 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV56077106, COSV56077864; called by muse, mutect2, varscan2
- ANO2 | c.2785A>G p.T929A (on ENST00000356134 / NM_001278597.3; = p.T933A on NM_001278596.3) | Missense Mutation (SNP) | VAF 76/222 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.062); catalogued as COSV59033408; called by muse, mutect2, varscan2
- ANO2 | c.1162A>C p.I388L (on ENST00000356134 / NM_001278597.3; = p.I392L on NM_001278596.3) | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.018); catalogued as COSV59033446; called by muse, mutect2, varscan2
- ANO2 | c.104A>G p.K35R (on ENST00000356134 / NM_001278597.3; = p.K39R on NM_001278596.3) | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0); catalogued as rs779917319, COSV59033463; called by mutect2, varscan2
- ANO3 | c.1540C>T p.R514C | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs1161758979, COSV56785162; called by muse, mutect2, varscan2
- ANO4 | c.196G>T p.E66* (on ENST00000392977 / NM_001286615.2; = p.E31* on NM_178826.4) | Nonsense Mutation (SNP) | VAF 42/132 reads (32%) | catalogued as COSV54596090, COSV54604820; called by muse, varscan2
- ANO4 | c.382T>G p.S128A (on ENST00000392977 / NM_001286615.2; = p.S93A on NM_178826.4) | Missense Mutation (SNP) | VAF 72/246 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs1292896797, COSV54604463, COSV54604831; called by muse, mutect2, varscan2
- ANO4 | c.850C>T p.R284C (on ENST00000392977 / NM_001286615.2; = p.R249C on NM_178826.4) | Missense Mutation (SNP) | VAF 70/242 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs780598682, COSV54585802; called by muse, mutect2, varscan2
- ANO4 | c.925C>T p.R309* (on ENST00000392977 / NM_001286615.2; = p.R274* on NM_178826.4) | Nonsense Mutation (SNP) | VAF 70/228 reads (31%) | catalogued as rs866684439, COSV104407411, COSV54586554; called by muse, mutect2, varscan2
- ANO4 | c.2492G>A p.R831Q (on ENST00000392977 / NM_001286615.2; = p.R796Q on NM_178826.4) | Missense Mutation (SNP) | VAF 50/168 reads (30%) | SIFT tolerated (0.63); PolyPhen benign (0.052); catalogued as rs868314489, COSV54590940; called by muse, mutect2, varscan2
- ANO5 | c.71C>A p.S24Y | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV100201923, COSV61087861; called by muse, mutect2, varscan2
- ANO5 | c.644G>T p.R215I | Missense Mutation (SNP) | VAF 77/260 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as COSV61087869; called by muse, mutect2, varscan2
- ANO8 | c.2894G>A p.R965H | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1236937826, COSV50179233; called by muse, mutect2, varscan2
- ANTXR2 | c.1183C>T p.R395C | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761958936, COSV56313905; called by muse, mutect2, varscan2
- ANTXR2 | c.413A>C p.K138T | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.042); catalogued as COSV55019892; called by muse, mutect2, varscan2
- ANXA2 | c.482C>T p.S161L | Missense Mutation (SNP) | VAF 65/191 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.041); catalogued as rs138727673; called by muse, mutect2, varscan2
- ANXA7 | c.961C>T p.R321C (on ENST00000372919 / NM_001320880.2; = p.R299C on NM_001156.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/152 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs763284965, COSV65823901; called by muse, mutect2, varscan2
- AOAH | c.964C>T p.R322C | Missense Mutation (SNP) | VAF 56/208 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs150438169, COSV51737665; called by muse, mutect2, varscan2
- AOX1 | c.1213C>A p.L405I | Missense Mutation (SNP) | VAF 18/326 reads (6%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.458); catalogued as COSV101021938; called by muse, mutect2
- AP000471.1 | c.137G>A p.R46Q | Missense Mutation (SNP) | VAF 30/80 reads (38%) | catalogued as rs372705970; called by muse, mutect2, varscan2
- AP002512.3 | c.803G>A p.G268D | Missense Mutation (SNP) | VAF 43/137 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.315); catalogued as COSV54407889, COSV54407929; called by muse, mutect2, varscan2
- AP002748.5 | c.188C>T p.A63V | Missense Mutation (SNP) | VAF 70/225 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs866558676, COSV59150407; called by muse, mutect2, varscan2
- AP1AR | c.506G>A p.R169Q | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.127); catalogued as rs746050291, COSV56769706; called by muse, mutect2, varscan2
- AP1G1 | c.598G>T p.E200* | Nonsense Mutation (SNP) | VAF 18/239 reads (8%) | catalogued as COSV100250402; called by muse, mutect2
- AP2B1 | c.127G>A p.V43M | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.231); catalogued as rs770755535, COSV52001300; called by muse, mutect2, varscan2
- AP2M1 | c.342G>T p.E114D | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV53049145; called by muse, mutect2, varscan2
- AP3B1 | c.1946G>A p.R649Q | Missense Mutation (SNP) | VAF 62/198 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748191084, COSV54877031; called by muse, mutect2, varscan2
- AP3B1 | c.1650G>A p.Q550= | Splice Region (SNP) | VAF 39/139 reads (28%) | catalogued as COSV54888145; called by muse, mutect2, varscan2
- AP3B2 | c.2902G>A p.V968I (on ENST00000261722; = p.V962I on NM_004644.5) | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.743); catalogued as rs764083003, COSV55611902; called by muse, varscan2
- AP4E1 | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs556357549, COSV55916749; called by muse, mutect2, varscan2
- APAF1 | c.1505C>A p.A502D (on ENST00000551964 / NM_181861.2; = p.A491D on NM_001160.3) | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV59666071; called by muse, mutect2, varscan2
- APBB1IP | c.619C>A p.L207I | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs766226916, COSV100770898, COSV63076537; called by muse, mutect2, varscan2
- APBB1IP | c.820T>C p.Y274H | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV66130408; called by muse, mutect2, varscan2
- APC | c.503G>T p.R168I | Missense Mutation (SNP) | VAF 39/115 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57334984, COSV57338113; called by muse, mutect2, varscan2
- APCDD1 | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.576); catalogued as rs771909445, COSV62372830; called by muse, mutect2, varscan2
- APMAP | c.367A>C p.K123Q | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.297); catalogued as COSV54175484; called by muse, mutect2, varscan2
- APOB | c.13075T>C p.F4359L | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV99265484; called by muse, mutect2, varscan2
- APOB | c.10525T>G p.Y3509D | Missense Mutation (SNP) | VAF 50/169 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51944166; called by muse, mutect2, varscan2
- APOB | c.9306C>A p.F3102L | Missense Mutation (SNP) | VAF 78/232 reads (34%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.908); catalogued as COSV51922023; called by muse, mutect2, varscan2
- APOB | c.7511C>A p.S2504Y | Missense Mutation (SNP) | VAF 16/292 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV51924144; called by muse, mutect2
- APOB | c.5686T>A p.F1896I | Missense Mutation (SNP) | VAF 118/331 reads (36%) | SIFT tolerated (0.96); PolyPhen benign (0.192); catalogued as COSV51944189; called by muse, mutect2, varscan2
- APOB | c.1094C>A p.S365Y | Missense Mutation (SNP) | VAF 74/259 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV51944197; called by muse, mutect2, varscan2
- APOBEC3F | c.1051T>C p.F351L | Missense Mutation (SNP) | VAF 111/365 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs757600612, COSV57911308; called by muse, mutect2, varscan2
- APOBEC3G | c.577C>A p.L193I | Missense Mutation (SNP) | VAF 50/144 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.823); catalogued as COSV68470544; called by muse, mutect2, varscan2
- APOL2 | c.214G>A p.D72N | Missense Mutation (SNP) | VAF 78/262 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.897); catalogued as rs757083546, COSV50772484; called by muse, mutect2, varscan2
- APOL3 | c.938G>A p.R313Q (on ENST00000349314 / NM_145640.2; = p.R242Q on NM_014349.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 59/146 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs773872410, COSV62580362; called by muse, mutect2, varscan2
- AQP12A | c.277G>T p.E93* | Nonsense Mutation (SNP) | VAF 8/24 reads (33%) | catalogued as rs200267757, COSV61837372; called by muse, mutect2, varscan2
- AQR | c.3053G>A p.R1018Q | Missense Mutation (SNP) | VAF 27/125 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs370660482, COSV50031222; called by muse, mutect2, varscan2
- AQR | c.842T>C p.V281A | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT tolerated (0.28); PolyPhen benign (0.043); catalogued as COSV50042019; called by muse, mutect2, varscan2
- ARAP1 | c.3901G>A p.D1301N (on ENST00000393609 / NM_001040118.2; = p.D1056N on NM_015242.4) | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1214366352, COSV61992848; called by muse, mutect2, varscan2
- ARAP2 | c.2884T>C p.Y962H | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.575); catalogued as rs139661928; called by muse, mutect2, varscan2
- ARAP2 | c.1984G>A p.E662K | Missense Mutation (SNP) | VAF 36/139 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); catalogued as rs947472819, COSV58285840; called by muse, mutect2, varscan2
- ARAP2 | c.1409T>C p.I470T | Missense Mutation (SNP) | VAF 46/171 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58289451; called by muse, mutect2, varscan2
- ARAP2 | c.751G>T p.E251* | Nonsense Mutation (SNP) | VAF 78/244 reads (32%) | catalogued as COSV58289457; called by muse, varscan2
- ARAP2 | c.653C>T p.S218F | Missense Mutation (SNP) | VAF 83/284 reads (29%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as COSV58281966, COSV58289462; called by muse, varscan2
- ARAP3 | c.2953C>T p.R985C | Missense Mutation (SNP) | VAF 14/254 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs866209168, COSV53351227; called by muse, mutect2
- ARCN1 | c.606G>T p.E202D | Missense Mutation (SNP) | VAF 38/145 reads (26%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV50616248; called by muse, mutect2, varscan2
- ARF5 | c.304G>T p.E102* | Nonsense Mutation (SNP) | VAF 6/58 reads (10%) | catalogued as COSV50001576; called by muse, mutect2, varscan2
- ARFGAP1 | c.280G>A p.D94N | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as rs557202365, COSV100796679, COSV62262451; called by muse, mutect2
- ARFGAP2 | c.1207G>A p.A403T | Missense Mutation (SNP) | VAF 44/125 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV53568370; called by muse, mutect2, varscan2
- ARFGEF1 | c.4225T>C p.F1409L | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51613004; called by muse, mutect2, varscan2
- ARFGEF1 | c.3815G>A p.R1272Q | Missense Mutation (SNP) | VAF 52/158 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV51602906, COSV99141102; called by muse, mutect2, varscan2
- ARFGEF1 | c.3557G>A p.R1186Q | Missense Mutation (SNP) | VAF 42/123 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51613017; called by muse, mutect2, varscan2
- ARFGEF2 | c.2039A>G p.Q680R | Missense Mutation (SNP) | VAF 67/191 reads (35%) | SIFT tolerated (0.61); PolyPhen benign (0.021); catalogued as COSV64213723; called by muse, mutect2, varscan2
- ARFGEF2 | c.5225T>G p.I1742S | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.254); catalogued as COSV64213727; called by muse, mutect2, varscan2
- ARFGEF3 | c.4841C>T p.A1614V | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs767280503, COSV52453788; called by muse, mutect2, varscan2
- ARFGEF3 | c.5769G>T p.E1923D | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.15); catalogued as rs1396357003, COSV52463810; called by muse, mutect2, varscan2
- ARFRP1 | c.110C>T p.S37L | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as rs1568771304, COSV60832851; called by muse, mutect2, varscan2
- ARHGAP10 | c.713G>A p.R238Q | Missense Mutation (SNP) | VAF 107/295 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs759498019, COSV60602830; called by muse, mutect2, varscan2
- ARHGAP11A | c.932G>T p.R311I | Missense Mutation (SNP) | VAF 27/115 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.133); catalogued as rs372419991; called by muse, varscan2
- ARHGAP12 | c.2249T>G p.F750C | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60964913; called by muse, mutect2, varscan2
- ARHGAP15 | c.673G>T p.E225* | Nonsense Mutation (SNP) | VAF 12/70 reads (17%) | catalogued as COSV54495270, COSV99710380, COSV99714277; called by muse, mutect2
- ARHGAP17 | c.633C>A p.F211L | Missense Mutation (SNP) | VAF 54/204 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.338); catalogued as COSV51509762; called by muse, mutect2, varscan2
- ARHGAP17 | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 66/198 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs757526992, COSV51509775; called by muse, mutect2, varscan2
- ARHGAP18 | c.1399A>C p.N467H | Missense Mutation (SNP) | VAF 56/206 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0.013); catalogued as COSV63765315; called by muse, mutect2, varscan2
- ARHGAP18 | c.983C>T p.A328V | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs191935343, COSV63765320; called by muse, mutect2, varscan2
- ARHGAP19 | c.765G>T p.K255N | Missense Mutation (SNP) | VAF 61/181 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.762); catalogued as COSV57394396; called by muse, mutect2, varscan2
- ARHGAP21 | c.4723G>A p.E1575K | Missense Mutation (SNP) | VAF 84/266 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.355); catalogued as rs373404445, COSV100255827; called by muse, mutect2, varscan2
- ARHGAP21 | c.1797T>G p.F599L | Missense Mutation (SNP) | VAF 121/343 reads (35%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV57608877; called by muse, mutect2, varscan2
- ARHGAP21 | c.1480C>T p.R494C | Missense Mutation (SNP) | VAF 86/269 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs751405078, COSV57608900; called by muse, mutect2, varscan2
- ARHGAP21 | c.990T>G p.I330M | Missense Mutation (SNP) | VAF 57/204 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.055); catalogued as COSV57608924; called by muse, mutect2, varscan2
- ARHGAP25 | c.794C>T p.A265V (on ENST00000409202 / NM_001007231.3; = p.A257V on NM_014882.3) | Missense Mutation (SNP) | VAF 11/192 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as rs1481204393, COSV54898666; called by muse, mutect2
- ARHGAP26 | c.1717G>A p.D573N | Missense Mutation (SNP) | VAF 94/291 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.014); catalogued as rs775284912, COSV50832978, COSV99189530; called by muse, mutect2, varscan2
- ARHGAP30 | c.2182A>C p.S728R | Missense Mutation (SNP) | VAF 145/509 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as COSV63514659; called by muse, mutect2, varscan2
- ARHGAP30 | c.492G>A p.M164I | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63517860; called by muse, mutect2, varscan2
- ARHGAP32 | c.3910C>T p.R1304C (on ENST00000310343 / NM_001378025.1; = p.R955C on NM_014715.4) | Missense Mutation (SNP) | VAF 33/127 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.009); catalogued as rs749894523, COSV59845005; called by muse, mutect2, varscan2
- ARHGAP32 | c.3621C>A p.F1207L (on ENST00000310343 / NM_001378025.1; = p.F858L on NM_014715.4) | Missense Mutation (SNP) | VAF 33/131 reads (25%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as COSV59851998; called by muse, mutect2, varscan2
- ARHGAP32 | c.857T>C p.V286A | Missense Mutation (SNP) | VAF 50/178 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as COSV59852017; called by muse, varscan2
- ARHGAP32 | c.529C>T p.R177W | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs762513902, COSV59852028; called by muse, mutect2, varscan2
- ARHGAP32 | c.235G>A p.A79T | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.943); catalogued as rs750991097, COSV59852040; called by muse, mutect2, varscan2
- ARHGAP35 | c.765A>C p.K255N | Missense Mutation (SNP) | VAF 40/106 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV68333393; called by muse, mutect2, varscan2
- ARHGAP36 | c.1318G>A p.V440M | Missense Mutation (SNP) | VAF 90/304 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs1191757469, COSV52266034, COSV52269379; called by muse, mutect2, varscan2
- ARHGAP4 | c.1530G>T p.E510D | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.014); catalogued as COSV63133250, COSV63134924; called by muse, mutect2, varscan2
- ARHGAP5 | c.399T>G p.I133M | Missense Mutation (SNP) | VAF 68/193 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV61537739; called by muse, mutect2, varscan2
- ARHGAP5 | c.2759C>T p.S920F | Missense Mutation (SNP) | VAF 67/209 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.661); catalogued as rs1420785475, COSV61537744; called by muse, mutect2, varscan2
- ARHGAP5 | c.3063T>G p.I1021M | Missense Mutation (SNP) | VAF 115/307 reads (37%) | SIFT tolerated (0.44); PolyPhen benign (0.129); catalogued as COSV61537748; called by muse, mutect2, varscan2
- ARHGAP6 | c.454G>A p.A152T | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV61632701; called by muse, varscan2
- ARHGAP6 | c.396G>T p.K132N | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.991); catalogued as COSV61631769; called by muse, varscan2
- ARHGDIB | c.581C>T p.S194L | Missense Mutation (SNP) | VAF 75/278 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.196); catalogued as rs774401441, COSV56763076; called by muse, mutect2, varscan2
- ARHGDIB | c.147G>T p.K49N | Missense Mutation (SNP) | VAF 80/471 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57456558; called by muse, mutect2, varscan2
- ARHGEF12 | c.2557C>T p.R853* | Nonsense Mutation (SNP) | VAF 67/211 reads (32%) | catalogued as COSV63106137; called by muse, mutect2, varscan2
- ARHGEF17 | c.1216T>C p.S406P | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as COSV55234973; called by muse, mutect2
- ARHGEF26 | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.059); catalogued as COSV62845591; called by muse, mutect2, varscan2
- ARHGEF26 | c.1081A>C p.K361Q | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs779880869, COSV62849093; called by muse, mutect2, varscan2
- ARHGEF26 | c.1930A>T p.I644F | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62849118; called by muse, mutect2, varscan2
- ARHGEF28 | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.991); catalogued as rs371272526; called by muse, mutect2, varscan2
- ARHGEF37 | c.427C>T p.R143W | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.417); catalogued as rs770631740, COSV100382318, COSV61368397; called by muse, mutect2, varscan2
- ARHGEF39 | c.823A>G p.K275E | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV58397585; called by muse, mutect2, varscan2
- ARHGEF4 | c.521A>C p.H174P | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as COSV58125787; called by muse, mutect2, varscan2
- ARHGEF4 | c.1111G>A p.D371N | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV58125801; called by muse, mutect2, varscan2
- ARHGEF4 | c.1426G>A p.D476N | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as COSV58125819; called by muse, mutect2, varscan2
- ARHGEF6 | c.1324G>A p.E442K | Missense Mutation (SNP) | VAF 41/147 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.26); catalogued as COSV51693719; called by muse, mutect2, varscan2
- ARHGEF7 | c.1488G>T p.K496N (on ENST00000375741 / NM_001113511.2; = p.K318N on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs530458692, COSV54547299; called by muse, mutect2, varscan2
- ARHGEF7 | c.2528A>C p.K843T (on ENST00000646102 / NM_001354046.1; = p.K627T on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.832); catalogued as COSV54547321; called by muse, mutect2, varscan2
- ARID1A | c.1776T>A p.Y592* | Nonsense Mutation (SNP) | VAF 55/196 reads (28%) | catalogued as COSV61383348, COSV61388053; called by muse, mutect2, varscan2
- ARID2 | c.1638T>G p.Y546* | Nonsense Mutation (SNP) | VAF 42/130 reads (32%) | catalogued as COSV57609730; called by muse, mutect2, varscan2
- ARID2 | c.2969C>T p.S990L | Missense Mutation (SNP) | VAF 73/218 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.163); catalogued as rs758368727, COSV57604758; called by muse, mutect2, varscan2
- ARID3A | c.988C>T p.R330W | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs145361495; called by muse, mutect2, varscan2
- ARID4A | c.644C>A p.S215* | Nonsense Mutation (SNP) | VAF 21/78 reads (27%) | catalogued as COSV62164947, COSV62165196; called by muse, mutect2, varscan2
- ARID4A | c.2359G>A p.E787K | Missense Mutation (SNP) | VAF 45/138 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as rs148135007; called by muse, mutect2, varscan2
- ARID5B | c.3409T>G p.S1137A | Missense Mutation (SNP) | VAF 78/247 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.675); catalogued as COSV54425499; called by muse, mutect2, varscan2
- ARL13A | c.774G>T p.K258N | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.946); catalogued as COSV65880222; called by muse, mutect2, varscan2
- ARL13B | c.235C>T p.R79W | Missense Mutation (SNP) | VAF 66/239 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs767393160, COSV57397362, COSV57402086; called by muse, mutect2, varscan2
- ARMCX2 | c.313G>A p.A105T | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.001); catalogued as rs369060938, COSV57530743; called by muse, mutect2, varscan2
- ARMCX3 | c.718A>G p.M240V | Missense Mutation (SNP) | VAF 120/400 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.349); catalogued as COSV57871155; called by muse, mutect2, varscan2
- ARMH3 | c.234T>G p.I78M | Missense Mutation (SNP) | VAF 15/196 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.901); catalogued as COSV100228899; called by muse, mutect2
- ARMH4 | c.2225G>T p.R742M | Missense Mutation (SNP) | VAF 47/120 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV50768302; called by muse, mutect2, varscan2
- ARMH4 | c.1386G>T p.E462D | Missense Mutation (SNP) | VAF 10/162 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99958134, COSV99958326; called by muse, mutect2
- ARMH4 | c.1285G>A p.D429N | Missense Mutation (SNP) | VAF 46/149 reads (31%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as COSV50764206; called by muse, mutect2, varscan2
- ARNTL | c.163G>T p.D55Y | Missense Mutation (SNP) | VAF 40/134 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as COSV62987704; called by muse, mutect2, varscan2
- ARNTL | c.907G>A p.E303K (on ENST00000403290 / NM_001297719.2; = p.E302K on NM_001178.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 58/196 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.026); catalogued as rs773491224, COSV100724712, COSV62986216; called by muse, mutect2, varscan2
- ARNTL2 | c.385G>T p.E129* | Nonsense Mutation (SNP) | VAF 73/266 reads (27%) | catalogued as COSV53827408; called by muse, mutect2, varscan2
- ARR3 | c.139C>T p.R47* | Nonsense Mutation (SNP) | VAF 59/198 reads (30%) | catalogued as rs1192044232, COSV57204706; called by muse, mutect2, varscan2
- ARSD | c.1021G>A p.E341K | Missense Mutation (SNP) | VAF 38/124 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.608); catalogued as rs750661580, COSV54201298; called by muse, mutect2, varscan2
- ARSF | c.311T>C p.V104A | Missense Mutation (SNP) | VAF 38/125 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.219); catalogued as rs1439919912, COSV63840347; called by muse, mutect2, varscan2
- ARSF | c.1750C>T p.R584W | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); catalogued as rs745851264, COSV63840352; called by muse, mutect2, varscan2
- ARSH | c.1255G>A p.D419N | Missense Mutation (SNP) | VAF 53/128 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.019); catalogued as COSV66963497; called by muse, mutect2, varscan2
- ARSI | c.1301G>A p.G434D | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.956); catalogued as COSV60817978; called by muse, mutect2, varscan2
- ARSJ | c.1451G>A p.R484Q | Missense Mutation (SNP) | VAF 35/113 reads (31%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.838); catalogued as rs761931068, COSV59538873; called by muse, mutect2, varscan2
- ARSJ | c.334A>G p.K112E | Missense Mutation (SNP) | VAF 62/227 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV59538882; called by muse, mutect2, varscan2
- ARSL | c.170G>T p.G57V | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV66965547; called by muse, mutect2, varscan2
- ART3 | c.923A>C p.K308T | Missense Mutation (SNP) | VAF 58/213 reads (27%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.001); catalogued as COSV61914859; called by muse, mutect2, varscan2
- AS3MT | c.691G>T p.V231F | Missense Mutation (SNP) | VAF 37/228 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54918006; called by muse, mutect2, varscan2
- ASAP2 | c.140A>G p.D47G | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV55635195; called by muse, mutect2, varscan2
- ASAP2 | c.1189G>T p.E397* | Nonsense Mutation (SNP) | VAF 48/137 reads (35%) | catalogued as COSV55635204; called by muse, mutect2, varscan2
- ASAP2 | c.1303G>A p.V435I | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as rs763213826, COSV55635210; called by muse, mutect2, varscan2
- ASB11 | c.157G>T p.E53* | Nonsense Mutation (SNP) | VAF 12/140 reads (9%) | catalogued as COSV60354669; called by muse, mutect2
- ASB14 | c.1609T>G p.L537V | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.565); catalogued as COSV55702193; called by muse, mutect2, varscan2
- ASB14 | c.1516C>T p.R506W | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.153); catalogued as rs147855564; called by muse, mutect2, varscan2
- ASB15 | c.1636C>T p.R546* | Nonsense Mutation (SNP) | VAF 71/202 reads (35%) | catalogued as rs1237485684, COSV51923543; called by muse, mutect2, varscan2
- ASB17 | c.530dup p.N177Kfs*21 | Frame Shift Ins (INS) | VAF 19/73 reads (26%) | catalogued as rs749460467; called by mutect2, varscan2
- ASB3 | c.754C>T p.H252Y | Missense Mutation (SNP) | VAF 87/306 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV55077783; called by muse, mutect2, varscan2
- ASB3 | c.279A>C p.K93N | Missense Mutation (SNP) | VAF 41/166 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.029); catalogued as COSV55077792; called by muse, mutect2, varscan2
- ASB4 | c.730G>A p.E244K | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.067); catalogued as COSV57946934; called by muse, mutect2, varscan2
- ASB5 | c.893G>A p.R298Q | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs533097681, COSV56672675, COSV56675068; called by muse, mutect2, varscan2
- ASB5 | c.244C>T p.R82C | Missense Mutation (SNP) | VAF 58/210 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs773694713, COSV56669643, COSV56675393; called by muse, mutect2, varscan2
- ASB7 | c.159C>A p.F53L | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT tolerated (0.84); PolyPhen probably damaging (0.95); catalogued as COSV58404093; called by muse, mutect2, varscan2
- ASCC3 | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 45/140 reads (32%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs752951712, COSV100225437, COSV61226544; called by muse, mutect2, varscan2
- ASH1L | c.4334A>C p.K1445T | Missense Mutation (SNP) | VAF 41/172 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.878); catalogued as COSV64210794; called by muse, mutect2, varscan2
- ASH1L | c.2985G>T p.K995N | Missense Mutation (SNP) | VAF 67/224 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.831); catalogued as COSV64210801; called by muse, mutect2, varscan2
- ASH1L | c.229G>T p.E77* | Nonsense Mutation (SNP) | VAF 288/952 reads (30%) | catalogued as COSV64205353; called by muse, mutect2, varscan2
- ASH2L | c.436C>A p.H146N | Missense Mutation (SNP) | VAF 55/192 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.32); catalogued as COSV51700680; called by muse, mutect2, varscan2
- ASIC4 | c.704A>G p.Y235C | Missense Mutation (SNP) | VAF 42/125 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV61732597; called by muse, mutect2, varscan2
- ASMT | c.687G>T p.Q229H (on ENST00000381229; = p.Q257H on NM_004043.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 102/309 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.549); catalogued as COSV67110112; called by muse, mutect2, varscan2
- ASPH | c.1424A>G p.K475R | Missense Mutation (SNP) | VAF 100/378 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.017); catalogued as COSV65245925; called by muse, mutect2, varscan2
- ASPM | c.10372G>T p.E3458* | Nonsense Mutation (SNP) | VAF 14/205 reads (7%) | catalogued as COSV99660313; called by muse, mutect2
- ASPM | c.7085T>C p.V2362A | Missense Mutation (SNP) | VAF 46/169 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.074); catalogued as rs1411369588, COSV54133865; called by muse, mutect2, varscan2
- ASTE1 | c.459T>G p.N153K | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.056); catalogued as COSV99393798; called by muse, varscan2
- ASTL | c.784G>A p.G262S | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753364550, COSV60904210; called by muse, mutect2, varscan2
- ASTN2 | c.2183C>T p.S728L (on ENST00000313400 / NM_001365069.1; = p.S677L on NM_014010.5) | Missense Mutation (SNP) | VAF 27/113 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs144736118; called by muse, mutect2, varscan2
- ASTN2 | c.1189G>A p.A397T (on ENST00000313400 / NM_001365069.1; = p.A346T on NM_014010.5) | Missense Mutation (SNP) | VAF 38/125 reads (30%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs764877571, COSV57797806; called by muse, mutect2, varscan2
- ASXL1 | c.1423G>A p.D475N | Missense Mutation (SNP) | VAF 48/153 reads (31%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as rs754658635, COSV60114379, COSV60121320; called by muse, mutect2, varscan2
- ASXL1 | c.2593G>A p.E865K | Missense Mutation (SNP) | VAF 61/203 reads (30%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.01); catalogued as rs147895689; called by muse, mutect2, varscan2
- ASXL2 | c.2810G>A p.G937E | Missense Mutation (SNP) | VAF 85/275 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1336667691, COSV55463120; called by muse, mutect2, varscan2
- ASXL3 | c.2585A>C p.K862T | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.158); catalogued as COSV52472864; called by muse, mutect2, varscan2
- ASXL3 | c.5465A>C p.K1822T | Missense Mutation (SNP) | VAF 52/229 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV52472876; called by muse, varscan2
- ATAD2 | c.2754T>G p.I918M | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.438); catalogued as COSV54884009; called by muse, mutect2, varscan2
- ATAD2 | c.1361A>C p.K454T | Missense Mutation (SNP) | VAF 77/246 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.15); catalogued as COSV54884020; called by muse, mutect2, varscan2
- ATAD2 | c.467G>A p.R156Q | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV54879779; called by muse, mutect2, varscan2
- ATAD2B | c.2851C>T p.R951* | Nonsense Mutation (SNP) | VAF 4/56 reads (7%) | catalogued as rs1324537078, COSV99477585; called by muse, mutect2
- ATAD2B | c.1952A>C p.Q651P | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.697); catalogued as COSV53202536; called by muse, mutect2, varscan2
- ATAD3B | c.300G>T p.E100D (on ENST00000308647; = p.E154D on NM_031921.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.971); catalogued as COSV58019839; called by muse, mutect2, varscan2
- ATAD5 | c.4943C>A p.S1648Y | Missense Mutation (SNP) | VAF 52/180 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs750828539, COSV58976692; called by muse, mutect2, varscan2
- ATAD5 | c.5405G>A p.R1802Q | Missense Mutation (SNP) | VAF 39/103 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58976698; called by muse, mutect2, varscan2
- ATF5 | c.743G>A p.R248H | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.486); catalogued as rs761046434, COSV61312902; called by muse, mutect2, varscan2
- ATF6 | c.971G>A p.R324H | Missense Mutation (SNP) | VAF 51/140 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764722601, COSV63406075; called by muse, mutect2, varscan2
- ATF6 | c.1127G>A p.R376Q | Missense Mutation (SNP) | VAF 51/168 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs754973294, COSV63405935; called by muse, mutect2, varscan2
- ATF6 | c.1714C>T p.R572* | Nonsense Mutation (SNP) | VAF 27/106 reads (25%) | catalogued as rs760001414, COSV63405877; called by muse, mutect2, varscan2
- ATG2B | c.5572C>T p.R1858* | Nonsense Mutation (SNP) | VAF 62/222 reads (28%) | catalogued as rs778403094, COSV55891447; called by muse, mutect2, varscan2
- ATG2B | c.3654C>A p.F1218L | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV55891458; called by muse, mutect2, varscan2
- ATG2B | c.2516C>T p.S839L | Missense Mutation (SNP) | VAF 39/152 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.035); catalogued as rs1290466158, COSV63423145; called by muse, mutect2, varscan2
- ATG7 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT tolerated (0.54); PolyPhen benign (0.121); catalogued as rs1203239812, COSV61612337; called by muse, mutect2, varscan2
- ATL1 | c.1665G>T p.K555N | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.023); catalogued as COSV61204556; called by muse, mutect2, varscan2
- ATM | c.211G>T p.E71* | Nonsense Mutation (SNP) | VAF 6/62 reads (10%) | catalogued as COSV99589505; called by muse, mutect2, varscan2
- ATM | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 41/143 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769166447, CM1314652, COSV53734045, COSV53758870; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATM | c.1100C>T p.S367F | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as COSV53758898; called by muse, mutect2, varscan2
- ATM | c.3061G>T p.V1021L | Missense Mutation (SNP) | VAF 22/292 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0.111); catalogued as COSV99589509; called by muse, mutect2
- ATM | c.3867G>T p.K1289N | Missense Mutation (SNP) | VAF 39/135 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.217); catalogued as COSV53748050; called by muse, mutect2, varscan2
- ATM | c.5435C>T p.A1812V | Missense Mutation (SNP) | VAF 75/224 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.209); catalogued as rs199885813, CD982460, COSV53742238; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATM | c.8338C>A p.L2780I | Missense Mutation (SNP) | VAF 33/196 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53758984; called by muse, mutect2, varscan2
- ATMIN | c.1270T>G p.F424V | Missense Mutation (SNP) | VAF 60/197 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV55146891; called by muse, mutect2, varscan2
- ATN1 | c.2518A>G p.K840E | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.932); catalogued as COSV63112135; called by muse, mutect2, varscan2
- ATP10A | c.3996G>T p.K1332N | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV63517910, COSV63519586; called by muse, mutect2, varscan2
- ATP10B | c.2782T>C p.S928P | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV59158781; called by muse, mutect2, varscan2
- ATP11A | c.848C>T p.S283F | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV52106636, COSV99369333; called by muse, mutect2, varscan2
- ATP11B | c.346G>T p.D116Y | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60030995; called by muse, mutect2, varscan2
- ATP11B | c.760G>T p.E254* | Nonsense Mutation (SNP) | VAF 17/63 reads (27%) | catalogued as COSV60026901; called by muse, mutect2, varscan2
- ATP11B | c.776C>T p.A259V | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.987); catalogued as rs778203393, COSV60026046; called by muse, varscan2
- ATP11B | c.889C>A p.L297I | Missense Mutation (SNP) | VAF 51/164 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV60031015; called by muse, mutect2, varscan2
- ATP11C | c.2794C>G p.H932D | Missense Mutation (SNP) | VAF 129/376 reads (34%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.864); catalogued as COSV100557850; called by muse, varscan2
- ATP11C | c.1026A>C p.K342N | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.033); catalogued as COSV59568721; called by muse, mutect2, varscan2
- ATP12A | c.77A>G p.D26G | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV104374389, COSV99517556; called by muse, mutect2, varscan2
- ATP12A | c.406A>G p.S136G | Missense Mutation (SNP) | VAF 152/570 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV54519607; called by muse, varscan2
- ATP12A | c.2726A>G p.Y909C | Missense Mutation (SNP) | VAF 45/140 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.44); catalogued as COSV54519620; called by muse, mutect2, varscan2
- ATP13A1 | c.3235C>T p.R1079W | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.786); catalogued as rs939627327, COSV52288874; called by muse, mutect2, varscan2
- ATP13A5 | c.3498A>C p.E1166D | Missense Mutation (SNP) | VAF 80/216 reads (37%) | SIFT tolerated (0.5); PolyPhen benign (0.045); catalogued as COSV53232369; called by muse, mutect2, varscan2
- ATP13A5 | c.1004A>C p.K335T | Missense Mutation (SNP) | VAF 92/264 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.901); catalogued as COSV60872063; called by muse, mutect2, varscan2
- ATP1A2 | c.2310G>T p.K770N | Missense Mutation (SNP) | VAF 99/334 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV63404861; called by muse, mutect2, varscan2
- ATP1A3 | c.1472A>G p.Y491C (on ENST00000545399 / NM_001256214.2; = p.Y478C on NM_152296.5) | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1177257433, COSV57489462; called by muse, mutect2, varscan2
- ATP1A4 | c.1837C>T p.R613C | Missense Mutation (SNP) | VAF 60/164 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs755473222, COSV63627384, COSV63627420; called by muse, mutect2, varscan2
- ATP2B1 | c.2287C>T p.R763* | Nonsense Mutation (SNP) | VAF 68/254 reads (27%) | catalogued as COSV53805728; called by muse, mutect2, varscan2
- ATP2B4 | c.1225T>G p.F409V | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV58180679; called by muse, mutect2, varscan2
- ATP5MF-PTCD1 | c.32A>C p.K11T | Missense Mutation (SNP) | VAF 16/222 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.787); catalogued as COSV99461701; called by muse, mutect2
- ATP6V0D2 | c.1000T>C p.C334R | Missense Mutation (SNP) | VAF 68/186 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53416322; called by muse, mutect2, varscan2
- ATP6V1C1 | c.872T>G p.F291C | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.748); catalogued as COSV67778504; called by muse, varscan2
- ATP6V1E1 | c.392G>A p.R131Q | Missense Mutation (SNP) | VAF 47/152 reads (31%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs144829775, COSV99494214; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP6V1E2 | c.665G>T p.R222I | Missense Mutation (SNP) | VAF 41/135 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV60576353; called by muse, mutect2, varscan2
- ATP6V1G3 | c.229A>G p.T77A | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.146); catalogued as rs112576263; called by muse, mutect2, varscan2
- ATP6V1H | c.871-1G>T p.X291_splice | Splice Site (SNP) | VAF 46/151 reads (30%) | catalogued as COSV62219279; called by muse, mutect2, varscan2
- ATP7A | c.1729T>C p.S577P | Missense Mutation (SNP) | VAF 162/568 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV58450163; called by muse, mutect2, varscan2
- ATP7A | c.3479C>T p.S1160L | Missense Mutation (SNP) | VAF 73/214 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs149576827, COSV58450181; called by muse, mutect2, varscan2
- ATP8A2 | c.1874G>A p.R625Q | Missense Mutation (SNP) | VAF 48/118 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54943115, COSV54966099; called by mutect2, varscan2
- ATP8A2 | c.2158C>T p.R720* | Nonsense Mutation (SNP) | VAF 34/117 reads (29%) | catalogued as rs1566306570, COSV54964589; called by muse, mutect2, varscan2
- ATP8B4 | c.2861A>C p.K954T | Missense Mutation (SNP) | VAF 49/126 reads (39%) | SIFT tolerated (0.41); PolyPhen benign (0.017); catalogued as COSV52719786; called by muse, mutect2, varscan2
- ATP8B4 | c.683A>G p.K228R | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.031); catalogued as COSV52719803; called by muse, mutect2, varscan2
- ATP9A | c.869G>A p.R290Q | Missense Mutation (SNP) | VAF 45/192 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.386); catalogued as rs761097614, COSV100124509, COSV58762928; called by muse, mutect2, varscan2
- ATP9B | c.347G>A p.R116H | Missense Mutation (SNP) | VAF 50/169 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763076944, COSV56956355; called by muse, mutect2, varscan2
- ATP9B | c.983G>A p.S328N | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.978); catalogued as COSV56956376, COSV56961933; called by muse, mutect2, varscan2
- ATP9B | c.1250C>A p.S417Y | Missense Mutation (SNP) | VAF 26/274 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100303506; called by muse, mutect2
- ATR | c.6818T>G p.I2273S | Missense Mutation (SNP) | VAF 20/240 reads (8%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV100638192; called by muse, mutect2
- ATR | c.2947G>A p.D983N | Missense Mutation (SNP) | VAF 62/172 reads (36%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.874); catalogued as rs537845660, COSV63387210, COSV63388887; called by muse, mutect2, varscan2
- ATRN | c.517C>T p.R173C | Missense Mutation (SNP) | VAF 174/555 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs758948800, COSV53527986; called by muse, mutect2, varscan2
- ATRX | c.4387G>A p.E1463K | Missense Mutation (SNP) | VAF 220/650 reads (34%) | SIFT tolerated (0.48); PolyPhen benign (0.045); catalogued as rs782295246, COSV64880141; called by muse, mutect2, varscan2
- ATXN3L | c.791A>G p.Q264R | Missense Mutation (SNP) | VAF 152/520 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as COSV101019378; called by muse, mutect2, varscan2
- ATXN7L2 | c.746A>C p.E249A | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV63992550; called by muse, mutect2, varscan2
- AVEN | c.418G>T p.D140Y | Missense Mutation (SNP) | VAF 42/128 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60736120; called by muse, mutect2, varscan2
- AVIL | c.1205T>C p.I402T | Missense Mutation (SNP) | VAF 40/121 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as rs372232621; called by muse, mutect2, varscan2
- AVIL | c.394G>A p.D132N | Missense Mutation (SNP) | VAF 44/128 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs529665441, COSV57682823; called by muse, mutect2, varscan2
- AVL9 | c.102C>A p.F34L | Missense Mutation (SNP) | VAF 71/285 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as COSV59464720; called by muse, mutect2, varscan2
- AWAT2 | c.205C>T p.R69W | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1414757758, COSV52143961; called by muse, mutect2, varscan2
- AXL | c.502C>T p.P168S | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56570024, COSV56571617; called by muse, mutect2, varscan2
- AXL | c.854C>T p.S285L | Missense Mutation (SNP) | VAF 66/244 reads (27%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs201003955, COSV56565179; called by muse, varscan2
- AZIN1 | c.320A>G p.N107S | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.105); catalogued as rs769197838, COSV61480773; called by muse, mutect2, varscan2
- AZIN2 | c.1256G>A p.R419Q | Missense Mutation (SNP) | VAF 44/134 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs745840314, COSV53858928; called by muse, mutect2, varscan2
- AZU1 | c.541C>T p.R181C | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs201652896, COSV52141841; called by muse, mutect2, varscan2
- B3GALNT2 | c.1090G>A p.E364K | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.116); catalogued as rs138436770; called by muse, mutect2, varscan2
- B3GALT1 | c.896G>A p.R299Q | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as rs756735753, COSV59908835; called by muse, mutect2, varscan2
- B3GLCT | c.658G>T p.E220* | Nonsense Mutation (SNP) | VAF 16/70 reads (23%) | catalogued as COSV58456867; called by muse, mutect2, varscan2
- B3GLCT | c.764C>A p.S255Y | Missense Mutation (SNP) | VAF 22/133 reads (17%) | SIFT tolerated (0.47); PolyPhen benign (0.02); catalogued as rs1182400359, COSV100587284, COSV58453460; ClinVar: uncertain significance; called by muse, varscan2
- B3GNT5 | c.1043T>A p.F348Y | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.261); catalogued as COSV58476494; called by muse, mutect2, varscan2
- B3GNT9 | c.709G>A p.G237R | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.02); catalogued as COSV54628286; called by muse, mutect2, varscan2
- B4GALNT3 | c.2677C>T p.R893W | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374659372, COSV99842747; called by muse, mutect2, varscan2
- B4GALT2 | c.1097C>T p.P366L | Missense Mutation (SNP) | VAF 47/109 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs751228190, COSV58842740; called by muse, mutect2, varscan2
- B4GALT3 | c.247C>A p.L83I | Missense Mutation (SNP) | VAF 211/667 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as COSV60527623, COSV60527892; called by muse, mutect2, varscan2
- BAALC | c.466G>T p.E156* (on ENST00000297574 / NM_001364874.1; = p.E121* on NM_024812.3) | Nonsense Mutation (SNP) | VAF 21/92 reads (23%) | catalogued as rs766189422, COSV52563547; called by muse, mutect2, varscan2
- BAAT | c.428G>T p.R143L | Missense Mutation (SNP) | VAF 69/219 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs953427538, COSV52290084; called by muse, mutect2, varscan2
- BACE2 | c.750C>A p.V250= | Splice Region (SNP) | VAF 20/132 reads (15%) | catalogued as COSV57741441; called by muse, mutect2, varscan2
- BACH1 | c.683G>T p.R228I | Missense Mutation (SNP) | VAF 88/310 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV54519948; called by muse, mutect2, varscan2
- BACH1 | c.841G>A p.E281K | Missense Mutation (SNP) | VAF 86/316 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as rs1257840097, COSV54517914; called by muse, mutect2, varscan2
- BACH2 | c.573C>A p.S191R | Missense Mutation (SNP) | VAF 42/139 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.081); catalogued as COSV57600955; called by muse, mutect2, varscan2
- BAG3 | c.467C>T p.A156V | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.129); catalogued as rs572038196, COSV100958226; called by muse, mutect2
- BAG4 | c.1189G>A p.V397I | Missense Mutation (SNP) | VAF 55/147 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs150352965; called by muse, mutect2, varscan2
- BAHD1 | c.41C>T p.S14L | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.307); catalogued as rs774459113, COSV69084290; called by muse, mutect2, varscan2
- BANF1 | c.65G>A p.S22N | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV56463908; called by muse, mutect2, varscan2
- BANK1 | c.1468T>C p.F490L | Missense Mutation (SNP) | VAF 63/153 reads (41%) | SIFT tolerated (0.6); PolyPhen benign (0.316); catalogued as COSV59846579; called by muse, mutect2, varscan2
- BARD1 | c.420G>T p.K140N | Missense Mutation (SNP) | VAF 57/189 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs758749603, COSV53613427; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BARX2 | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); catalogued as COSV55649391; called by muse, mutect2, varscan2
- BASP1 | c.11A>C p.K4T | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59471599; called by muse, mutect2, varscan2
- BAZ1A | c.2758G>A p.E920K | Missense Mutation (SNP) | VAF 45/139 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as COSV100701203, COSV62411268; called by muse, mutect2, varscan2
- BAZ1A | c.2494C>A p.L832I | Missense Mutation (SNP) | VAF 58/166 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV62411275; called by muse, mutect2, varscan2
- BAZ1A | c.296C>T p.S99L | Missense Mutation (SNP) | VAF 54/353 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.307); catalogued as rs756584573, COSV62409855; called by muse, mutect2, varscan2
- BAZ1B | c.1718G>T p.R573I | Missense Mutation (SNP) | VAF 167/519 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.241); catalogued as COSV59992645; called by muse, varscan2
- BAZ1B | c.1633G>T p.E545* | Nonsense Mutation (SNP) | VAF 142/395 reads (36%) | catalogued as rs1423926578, COSV59992654; called by muse, varscan2
- BAZ1B | c.1632A>C p.K544N | Missense Mutation (SNP) | VAF 110/394 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.395); catalogued as COSV59992659; called by muse, varscan2
- BAZ1B | c.957G>T p.K319N | Missense Mutation (SNP) | VAF 40/143 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV59992669; called by muse, mutect2, varscan2
- BAZ2A | c.3125G>A p.R1042H | Missense Mutation (SNP) | VAF 49/196 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1241518092, COSV51632109; called by muse, mutect2, varscan2
- BBS10 | c.1073C>T p.S358L | Missense Mutation (SNP) | VAF 38/136 reads (28%) | SIFT tolerated (0.82); PolyPhen benign (0.007); catalogued as COSV53881041; called by muse, mutect2, varscan2
- BBS12 | c.599T>G p.F200C | Missense Mutation (SNP) | VAF 43/133 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV58562604; called by muse, mutect2, varscan2
- BBS12 | c.1802C>A p.T601N | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.697); catalogued as COSV58562610; called by muse, mutect2, varscan2
- BBS2 | c.1865G>A p.R622Q | Missense Mutation (SNP) | VAF 114/394 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs759714501, COSV55327535; called by muse, mutect2, varscan2
- BCAS4 | c.613G>A p.V205I | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.015); catalogued as rs564853296, COSV52813195; called by muse, mutect2, varscan2
- BCHE | c.997A>G p.I333V | Missense Mutation (SNP) | VAF 36/122 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs765307050, COSV52259530; called by muse, mutect2, varscan2
- BCKDHB | c.1160G>A p.R387Q | Missense Mutation (SNP) | VAF 49/160 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as rs755159101, COSV57512539; called by muse, mutect2, varscan2
- BCL10 | c.258T>G p.I86M | Missense Mutation (SNP) | VAF 62/196 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV65354063; called by muse, varscan2
- BCL10 | c.73C>T p.R25C | Missense Mutation (SNP) | VAF 48/186 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV65354068; called by muse, varscan2
- BCL11A | c.451C>A p.L151I (on ENST00000335712 / NM_001365609.1; = p.L185I on NM_018014.4) | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV59633815; called by muse, mutect2, varscan2
- BCL2L11 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as COSV58031267; called by muse, mutect2, varscan2
- BCL6 | c.929A>G p.D310G | Missense Mutation (SNP) | VAF 57/149 reads (38%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.989); catalogued as COSV51654059; called by muse, mutect2, varscan2
9,034 further variants in this file (6,842 protein-altering or splice-affecting, 1,944 silent, 248 other) are not listed here.
